Somatic mutation profile of cancer-model specimen HCM-BROD-0724-C43-85M (Adherent Cell Line, passage 8; aliquot HCM-BROD-0724-C43-85M-01D-A85C-36), derived from the metastatic tumor of HCMI case HCM-BROD-0724-C43, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 74.4 years (27,189 days).
Specimen HCM-BROD-0724-C43-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 8.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 92445d90-3e74-45e3-aa42-12900957c343.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0724-C43-10A (Blood Derived Normal), aliquot HCM-BROD-0724-C43-10A-01D-A85C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6100e6bd-4447-4681-b87c-7bda388c768b

The open-access MAF lists 2,530 somatic variants for this specimen: 1,612 protein-altering or splice-affecting, 817 silent, 101 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,458, Silent 817, Nonsense Mutation 95, Intron 54, Splice Region 25, Splice Site 18, 3'UTR 13, 5'Flank 12, Frame Shift Del 8, 5'UTR 8, RNA 8, 3'Flank 6.

Variants (750 of 2,530; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC6 | c.4375C>T p.R1459C | Missense Mutation (SNP) | VAF 198/648 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs72547524, CM030403; ClinVar: uncertain significance / pathogenic; called by muse, varscan2
- CDKN2A | c.238C>T p.R80* | Nonsense Mutation (SNP) | VAF 769/772 reads (100%) | hotspot (GDC flag); catalogued as rs121913388, CM014695, COSV58682746, COSV58721651; ClinVar: risk factor / likely pathogenic; called by muse, mutect2, varscan2
- CLDN16 | c.494C>T p.S165F | Missense Mutation (SNP) | VAF 530/724 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs104893728, CM076116, CM993501; ClinVar: pathogenic; called by muse, varscan2
- MED23 | c.3982C>T p.R1328C | Missense Mutation (SNP) | VAF 308/310 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs766478634, COSV51580995; ClinVar: likely pathogenic; called by muse, varscan2
- MYBPC1 | c.877C>T p.R293* (on ENST00000550270 / NM_206820.2; = p.R318* on NM_002465.4) | Nonsense Mutation (SNP) | VAF 69/252 reads (27%) | catalogued as rs397515422, CM129132, COSV62250776; ClinVar: pathogenic; called by muse, varscan2
- NF1 | c.6705-1G>A p.X2235_splice (on ENST00000358273 / NM_001042492.3; = p.X2214_splice on NM_000267.3) | Splice Site (SNP) | VAF 222/223 reads (100%) | catalogued as rs1060500356, CS000886, COSV62198415; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.298C>T p.Q100* | Nonsense Mutation (SNP) | VAF 719/723 reads (99%) | catalogued as rs1567555994, CM156961, COSV52702138, COSV53867973; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA12 | c.470G>A p.G157D | Missense Mutation (SNP) | VAF 158/254 reads (62%) | SIFT tolerated (0.28); PolyPhen benign (0.022); catalogued as COSV99790847; called by muse, mutect2, varscan2
- ABCA9 | c.4390C>T p.R1464W | Missense Mutation (SNP) | VAF 228/564 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs374873743; called by muse, varscan2
- ABCB7 | c.198G>A p.W66* (on ENST00000373394 / NM_001271696.3; = p.W67* on NM_004299.6) | Nonsense Mutation (SNP) | VAF 88/230 reads (38%) | catalogued as COSV53723309; called by muse, varscan2
- ACAD10 | c.1838C>T p.P613L | Missense Mutation (SNP) | VAF 174/572 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs1279452264; called by muse, varscan2
- ACAP3 | c.421C>T p.Q141* | Nonsense Mutation (SNP) | VAF 226/1238 reads (18%) | catalogued as COSV100686591; called by muse, varscan2
- ACE2 | c.1063G>A p.D355N | Missense Mutation (SNP) | VAF 231/508 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs961360700; called by muse, mutect2, varscan2
- ACSL4 | c.298G>A p.E100K (on ENST00000340800 / NM_022977.2; = p.E59K on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 117/547 reads (21%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.881); catalogued as COSV61615832, COSV61615891; called by muse, mutect2, varscan2
- ACSM1 | c.1709G>A p.R570Q | Missense Mutation (SNP) | VAF 92/274 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as rs201624784; called by muse, mutect2, varscan2
- ACSS3 | c.1531G>A p.G511R | Missense Mutation (SNP) | VAF 96/302 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99699369; called by muse, mutect2, varscan2
- ADAMTS20 | c.1753C>T p.R585C | Missense Mutation (SNP) | VAF 189/288 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs746899207, COSV67125941; called by muse, mutect2, varscan2
- ADAMTS9 | c.5231G>A p.R1744K | Missense Mutation (SNP) | VAF 322/426 reads (76%) | SIFT tolerated (0.94); PolyPhen benign (0.001); catalogued as COSV55788685; called by muse, varscan2
- ADCY8 | c.2200C>T p.P734S | Missense Mutation (SNP) | VAF 84/474 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.718); catalogued as rs866330045, COSV53912362; called by muse, varscan2
- ADCY8 | c.1246C>T p.L416F | Missense Mutation (SNP) | VAF 62/318 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53895961, COSV99654440; called by muse, varscan2
- ADGRF4 | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 75/443 reads (17%) | SIFT tolerated (0.71); PolyPhen benign (0.021); catalogued as COSV51950717; called by muse, mutect2, varscan2
- ADGRG4 | c.3524C>T p.S1175F | Missense Mutation (SNP) | VAF 402/834 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.307); catalogued as COSV104381527; called by muse, varscan2
- ADGRV1 | c.7644G>A p.M2548I | Missense Mutation (SNP) | VAF 307/406 reads (76%) | SIFT tolerated (0.22); PolyPhen benign (0.05); catalogued as COSV67988752; called by muse, mutect2, varscan2
- ADH1A | c.620C>T p.S207F | Missense Mutation (SNP) | VAF 168/572 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV52925787; called by muse, varscan2
- ADH1C | c.797C>T p.S266L | Missense Mutation (SNP) | VAF 429/448 reads (96%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs1005267020, COSV72463393; called by muse, mutect2, varscan2
- ADH1C | c.142C>T p.R48C | Missense Mutation (SNP) | VAF 280/281 reads (100%) | SIFT tolerated (0.06); PolyPhen benign (0.029); catalogued as rs759025388, COSV72463545; called by muse, mutect2, varscan2
- ADHFE1 | c.674C>T p.P225L | Missense Mutation (SNP) | VAF 125/815 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs776500463, COSV52556912; called by muse, mutect2, varscan2
- ADRB2 | c.1189G>A p.D397N | Missense Mutation (SNP) | VAF 234/318 reads (74%) | SIFT tolerated (0.58); PolyPhen benign (0.038); catalogued as rs777431854; called by muse, mutect2, varscan2
- AFF3 | c.1037C>T p.P346L | Missense Mutation (SNP) | VAF 82/288 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.197); catalogued as COSV100419826; called by muse, varscan2
- AFM | c.1056G>A p.A352= | Splice Region (SNP) | VAF 70/224 reads (31%) | catalogued as rs141061547; called by muse, varscan2
- AGAP2 | c.667G>A p.G223R | Missense Mutation (SNP) | VAF 558/872 reads (64%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.5); catalogued as rs1253577497; called by muse, varscan2
- AGBL3 | c.1762G>A p.E588K | Missense Mutation (SNP) | VAF 165/1022 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.012); catalogued as COSV51951384; called by muse, mutect2, varscan2
- AGK | c.516C>T p.V172= | Splice Region (SNP) | VAF 236/472 reads (50%) | catalogued as COSV100814740; called by muse, varscan2
- AGO2 | c.1903C>T p.R635W | Missense Mutation (SNP) | VAF 179/918 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs760721583; called by muse, varscan2
- AGTR1 | c.920A>T p.K307I | Missense Mutation (SNP) | VAF 101/577 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV62558064; called by muse, mutect2, varscan2
- AGTR2 | c.920G>A p.G307E | Missense Mutation (SNP) | VAF 354/786 reads (45%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.992); catalogued as rs868921732, COSV64156893; called by muse, varscan2
- AHNAK2 | c.5201G>A p.G1734E | Missense Mutation (SNP) | VAF 125/784 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1204288052; called by muse, varscan2
- AK7 | c.706G>A p.E236K | Missense Mutation (SNP) | VAF 235/669 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as rs114393353, COSV50870705, COSV50881490; called by muse, varscan2
- AKAP10 | c.46C>T p.R16C | Missense Mutation (SNP) | VAF 371/792 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1465814541; called by muse, mutect2, varscan2
- AKAP6 | c.5093C>T p.S1698F | Missense Mutation (SNP) | VAF 326/556 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55229491, COSV99802282; called by muse, mutect2, varscan2
- AKR1C4 | c.473G>A p.G158E | Missense Mutation (SNP) | VAF 114/370 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV54122293, COSV54122714; called by muse, mutect2, varscan2
- AKR1D1 | c.238G>A p.E80K | Missense Mutation (SNP) | VAF 236/461 reads (51%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.463); catalogued as COSV54336211; called by muse, varscan2
- AKR1D1 | c.371C>T p.A124V | Missense Mutation (SNP) | VAF 196/408 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.699); catalogued as COSV54337027; called by muse, varscan2
- AL645922.1 | c.605G>A p.R202Q | Missense Mutation (SNP) | VAF 141/1028 reads (14%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs145799939; called by muse, mutect2, varscan2
- ALMS1 | c.494C>T p.S165F | Missense Mutation (SNP) | VAF 329/561 reads (59%) | SIFT deleterious (0.03); PolyPhen benign (0.333); catalogued as COSV52513880; called by muse, mutect2, varscan2
- AMY2A | c.844C>T p.R282C | Missense Mutation (SNP) | VAF 265/1424 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.3); catalogued as rs768370675; called by muse, varscan2
- ANKRD2 | c.429C>T p.I143= | Splice Region (SNP) | VAF 125/497 reads (25%) | catalogued as COSV53967782; called by muse, mutect2, varscan2
- ANKRD20A1 | c.1952C>T p.S651F | Missense Mutation (SNP) | VAF 117/625 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.588); catalogued as rs751997383; called by muse, mutect2, varscan2
- ANKRD30A | c.802C>T p.H268Y (on ENST00000611781; = p.H212Y on NM_052997.2) | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs1167241084, COSV64610990; called by muse, mutect2, varscan2
- ANO1 | c.2603G>A p.R868Q | Missense Mutation (SNP) | VAF 215/215 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100796915; called by muse, mutect2, varscan2
- ANO2 | c.2278C>T p.P760S (on ENST00000356134 / NM_001278597.3; = p.P764S on NM_001278596.3) | Missense Mutation (SNP) | VAF 120/439 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV59037720; called by muse, mutect2, varscan2
- ANO3 | c.968C>T p.S323L | Missense Mutation (SNP) | VAF 57/206 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.313); catalogued as COSV99882809; called by muse, mutect2, varscan2
- ANO4 | c.2524G>A p.E842K (on ENST00000392977 / NM_001286615.2; = p.E807K on NM_178826.4) | Missense Mutation (SNP) | VAF 122/476 reads (26%) | SIFT tolerated (0.68); PolyPhen benign (0.012); catalogued as COSV54598610; called by muse, varscan2
- ANPEP | c.272C>T p.P91L | Missense Mutation (SNP) | VAF 276/484 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs372186369; called by muse, varscan2
- AP2A1 | c.2207C>T p.P736L | Missense Mutation (SNP) | VAF 412/600 reads (69%) | SIFT tolerated (0.95); PolyPhen probably damaging (0.981); catalogued as rs371119628; called by muse, varscan2
- APC | c.4639G>A p.E1547K | Missense Mutation (SNP) | VAF 91/390 reads (23%) | SIFT tolerated (0.48); PolyPhen benign (0.027); catalogued as COSV57322083, COSV57329454; called by muse, mutect2, varscan2
- APOB | c.12175G>A p.E4059K | Missense Mutation (SNP) | VAF 256/720 reads (36%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.886); catalogued as rs756040945, COSV51956358; called by muse, varscan2
- ARAF | c.976C>T p.R326* | Nonsense Mutation (SNP) | VAF 420/888 reads (47%) | catalogued as rs1452639448, COSV99283501; called by muse, varscan2
- ARFGEF3 | c.3229C>T p.P1077S | Missense Mutation (SNP) | VAF 785/790 reads (99%) | SIFT tolerated (0.11); PolyPhen benign (0.013); catalogued as rs1293796751; called by muse, varscan2
- ARHGEF5 | c.2473C>T p.P825S | Missense Mutation (SNP) | VAF 161/1315 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1412421161; called by muse, mutect2, varscan2
- ARMC4 | c.3089A>T p.N1030I | Missense Mutation (SNP) | VAF 148/502 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV59474314; called by muse, varscan2
- ARMC5 | c.331C>T p.P111S | Missense Mutation (SNP) | VAF 482/748 reads (64%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.003); catalogued as rs1473312567; called by muse, varscan2
- ARMCX2 | c.1336G>A p.E446K | Missense Mutation (SNP) | VAF 380/821 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); catalogued as COSV57530721; called by muse, varscan2
- ARSF | c.263G>A p.G88E | Missense Mutation (SNP) | VAF 163/725 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1390921374; called by muse, varscan2
- ARSF | c.841G>A p.E281K | Missense Mutation (SNP) | VAF 140/301 reads (47%) | SIFT tolerated (0.55); PolyPhen benign (0.01); catalogued as COSV63840443; called by muse, mutect2, varscan2
- ASNSD1 | c.1651C>T p.P551S | Missense Mutation (SNP) | VAF 149/257 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53623847; called by muse, mutect2, varscan2
- ASTN1 | c.613C>T p.P205S | Missense Mutation (SNP) | VAF 530/531 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs145957941, COSV56082361; called by muse, mutect2, varscan2
- ATG4C | c.238C>T p.R80C | Missense Mutation (SNP) | VAF 79/417 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs146646910; called by muse, mutect2, varscan2
- ATP11C | c.3347C>T p.S1116L | Missense Mutation (SNP) | VAF 112/250 reads (45%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.14); catalogued as COSV59560413, COSV59564678; called by muse, mutect2, varscan2
- ATP13A5 | c.2348C>T p.S783L | Missense Mutation (SNP) | VAF 131/676 reads (19%) | SIFT tolerated (0.45); PolyPhen benign (0.034); catalogued as rs1390039197; called by muse, varscan2
- ATP13A5 | c.247C>T p.Q83* | Nonsense Mutation (SNP) | VAF 52/336 reads (15%) | catalogued as COSV60875657; called by muse, mutect2, varscan2
- ATP2B2 | c.2053G>A p.E685K (on ENST00000352432; = p.E651K on NM_001683.5) | Missense Mutation (SNP) | VAF 142/736 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.093); catalogued as rs752661102, COSV59493351; called by muse, varscan2
- ATP6AP2 | c.1040G>A p.R347Q (on ENST00000378438; = p.R348Q on NM_005765.3) | Missense Mutation (SNP) | VAF 179/388 reads (46%) | SIFT tolerated (0.05); PolyPhen benign (0.083); catalogued as COSV65797616; called by muse, mutect2, varscan2
- ATP6V0D2 | c.142C>T p.H48Y | Missense Mutation (SNP) | VAF 60/406 reads (15%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.741); catalogued as COSV53412881; called by muse, mutect2
- ATRNL1 | c.3962C>T p.T1321I | Missense Mutation (SNP) | VAF 195/488 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as COSV58089797; called by muse, mutect2, varscan2
- AXIN2 | c.319A>C p.T107P | Missense Mutation (SNP) | VAF 192/1155 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.993); catalogued as COSV61057069; called by muse, mutect2, varscan2
- AXL | c.854C>T p.S285L | Missense Mutation (SNP) | VAF 472/1049 reads (45%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs201003955, COSV56565179; called by muse, varscan2
- BFAR | c.286C>T p.P96S | Missense Mutation (SNP) | VAF 264/695 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as rs752398303, COSV55492550; called by muse, mutect2, varscan2
- BHMT2 | c.1016G>A p.R339Q | Missense Mutation (SNP) | VAF 57/259 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as rs746838767; called by muse, mutect2, varscan2
- BMP6 | c.1142G>A p.R381Q | Missense Mutation (SNP) | VAF 363/1013 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.769); catalogued as rs200811682; called by muse, varscan2
- BRAF | c.532C>T p.R178* | Nonsense Mutation (SNP) | VAF 123/1180 reads (10%) | catalogued as rs770494089, COSV56105105, COSV56366111; called by muse, mutect2
- BRINP2 | c.1840G>A p.E614K | Missense Mutation (SNP) | VAF 384/386 reads (99%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV64177234; called by muse, mutect2, varscan2
- BTBD16 | c.232G>A p.G78R | Missense Mutation (SNP) | VAF 104/351 reads (30%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as COSV53262020; called by muse, mutect2, varscan2
- BTBD8 | c.871G>A p.G291R | Missense Mutation (SNP) | VAF 13/155 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61544949; called by muse, mutect2
- BTBD8 | c.1163G>A p.R388K | Missense Mutation (SNP) | VAF 346/485 reads (71%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.955); catalogued as rs1273079375; called by muse, mutect2, varscan2
- BTBD8 | c.5137G>A p.D1713N (on ENST00000636805 / NM_001376131.1; = p.D1200N on NM_015237.4) | Missense Mutation (SNP) | VAF 77/471 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV64885867; called by muse, mutect2, varscan2
- BTC | c.317G>A p.R106K | Missense Mutation (SNP) | VAF 268/437 reads (61%) | SIFT tolerated (0.19); PolyPhen benign (0.16); catalogued as rs782142077; called by muse, varscan2
- BTNL3 | c.1256C>T p.S419F | Missense Mutation (SNP) | VAF 113/480 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs1468570079, COSV61564583; called by muse, mutect2, varscan2
- C12orf40 | c.1805C>T p.S602F | Missense Mutation (SNP) | VAF 233/393 reads (59%) | SIFT tolerated (0.56); PolyPhen benign (0.234); catalogued as COSV61130335, COSV61130894; called by muse, mutect2, varscan2
- C12orf42 | c.544C>T p.P182S | Missense Mutation (SNP) | VAF 109/372 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.861); catalogued as COSV59379932; called by muse, mutect2, varscan2
- C16orf74 | c.17C>T p.S6F | Missense Mutation (SNP) | VAF 48/202 reads (24%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.776); catalogued as rs777069044; called by muse, mutect2, varscan2
- C1QTNF9 | c.227G>A p.R76Q | Missense Mutation (SNP) | VAF 112/662 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs779386798, COSV59656776; called by muse, varscan2
- C1QTNF9B | c.227G>A p.R76Q | Missense Mutation (SNP) | VAF 24/226 reads (11%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as rs1463638854, COSV65943913; called by muse, mutect2
- C1orf127 | c.2302G>A p.G768R | Missense Mutation (SNP) | VAF 191/1282 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.332); catalogued as rs1277091047; called by muse, varscan2
- C2orf78 | c.883G>A p.G295R | Missense Mutation (SNP) | VAF 185/516 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.059); catalogued as rs780803582, COSV68518201; called by muse, mutect2, varscan2
- CA10 | c.256C>T p.R86C | Missense Mutation (SNP) | VAF 370/774 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); catalogued as rs767808441, COSV53350762; called by muse, varscan2
- CABS1 | c.916G>A p.E306K | Missense Mutation (SNP) | VAF 361/361 reads (100%) | SIFT tolerated (0.06); PolyPhen benign (0.067); catalogued as COSV99909105; called by muse, varscan2
- CACNA1B | c.1634C>T p.S545F | Missense Mutation (SNP) | VAF 325/326 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1051482739; called by muse, mutect2, varscan2
- CACNA1D | c.6259G>A p.E2087K (on ENST00000350061 / NM_001128840.3; = p.E2107K on NM_000720.4) | Missense Mutation (SNP) | VAF 130/682 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.995); catalogued as rs762059527, COSV55436089, COSV55439012; called by muse, mutect2, varscan2
- CACNA2D1 | c.2038C>T p.L680F (on ENST00000356253 / NM_001366867.1; = p.L668F on NM_000722.4) | Missense Mutation (SNP) | VAF 398/592 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.488); catalogued as COSV62393667; called by muse, varscan2
- CACNA2D4 | c.253G>A p.G85S | Missense Mutation (SNP) | VAF 265/426 reads (62%) | SIFT tolerated (0.14); PolyPhen benign (0.337); catalogued as rs555700156, COSV54957400; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CADM2 | c.241C>T p.R81C (on ENST00000407528 / NM_001167674.2; = p.R83C on NM_153184.4) | Missense Mutation (SNP) | VAF 122/592 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs139991481, COSV67406856; called by muse, mutect2, varscan2
- CAMK2A | c.1297C>T p.R433C (on ENST00000348628 / NM_171825.2; = p.R444C on NM_015981.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 424/574 reads (74%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.999); catalogued as rs767291853, COSV62245779; called by muse, varscan2
- CAMK2B | c.1700C>T p.S567L | Missense Mutation (SNP) | VAF 258/552 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.327); catalogued as rs981667182, COSV99323036; called by muse, varscan2
- CAMSAP3 | c.1052C>T p.S351F | Missense Mutation (SNP) | VAF 204/505 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs926396897; called by muse, varscan2
- CAPN10 | c.1217C>A p.S406* | Nonsense Mutation (SNP) | VAF 374/546 reads (68%) | catalogued as COSV54376964; called by muse, varscan2
- CAPN6 | c.263C>T p.S88F | Missense Mutation (SNP) | VAF 294/595 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60694486; called by muse, varscan2
- CARD11 | c.1246G>A p.E416K | Missense Mutation (SNP) | VAF 196/783 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.588); catalogued as rs1562490836, COSV67801341; called by muse, varscan2
- CARMIL2 | c.2573C>T p.A858V | Missense Mutation (SNP) | VAF 72/237 reads (30%) | SIFT tolerated (0.7); PolyPhen benign (0.012); catalogued as COSV58029732; called by muse, mutect2, varscan2
- CARMIL2 | c.4121G>A p.R1374Q | Missense Mutation (SNP) | VAF 141/225 reads (63%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.795); catalogued as rs1372728652, COSV54667398; called by muse, mutect2, varscan2
- CASR | c.1132G>A p.E378K | Missense Mutation (SNP) | VAF 633/822 reads (77%) | SIFT tolerated (0.15); PolyPhen benign (0.163); catalogued as rs201338034, COSV56137031; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CASZ1 | c.4786G>A p.E1596K | Missense Mutation (SNP) | VAF 476/1509 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.31); catalogued as COSV65458762; called by muse, varscan2
- CATSPERB | c.1743G>A p.G581= | Splice Region (SNP) | VAF 150/366 reads (41%) | catalogued as COSV99830736; called by muse, varscan2
- CATSPERB | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 54/280 reads (19%) | SIFT tolerated (0.36); PolyPhen benign (0.167); catalogued as rs267604094, COSV56425352; called by muse, mutect2, varscan2
- CBL | c.1096-1G>A p.X366_splice | Splice Site (SNP) | VAF 96/98 reads (98%) | catalogued as CD1314297, CS099550, CS150637, COSV50631547, COSV50635311, COSV50641081; called by muse, mutect2, varscan2
- CBL | c.1096G>A p.E366K | Missense Mutation (SNP) | VAF 104/108 reads (96%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs1245863855, COSV50657369, COSV50665310; called by muse, mutect2, varscan2
- CCDC146 | c.1228C>T p.H410Y | Missense Mutation (SNP) | VAF 138/711 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.259); catalogued as COSV53551138; called by muse, mutect2, varscan2
- CCDC158 | c.2617C>T p.H873Y | Missense Mutation (SNP) | VAF 310/312 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs772275545; called by muse, mutect2, varscan2
- CCDC168 | c.1474C>T p.P492S | Missense Mutation (SNP) | VAF 246/374 reads (66%) | SIFT tolerated (0.45); PolyPhen benign (0.303); catalogued as rs1206816544; called by muse, mutect2, varscan2
- CCDC85A | c.808C>T p.R270C | Missense Mutation (SNP) | VAF 624/1072 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.232); catalogued as rs764849312, COSV68154259; called by muse, varscan2
- CCDC88C | c.6049G>A p.D2017N | Missense Mutation (SNP) | VAF 340/804 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1251025859, COSV57796472; called by muse, varscan2
- CCKAR | c.1132C>T p.R378C | Missense Mutation (SNP) | VAF 384/563 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55164304; called by muse, varscan2
- CCNE1 | c.559C>T p.L187F | Missense Mutation (SNP) | VAF 313/455 reads (69%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.751); catalogued as COSV99388473; called by muse, varscan2
- CD101 | c.853C>T p.Q285* | Nonsense Mutation (SNP) | VAF 276/365 reads (76%) | catalogued as COSV56716421, COSV56717203; called by muse, mutect2, varscan2
- CD2 | c.583G>A p.E195K | Missense Mutation (SNP) | VAF 108/512 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.03); catalogued as rs1167182650, COSV65644093; called by muse, varscan2
- CD36 | c.198G>A p.W66* | Nonsense Mutation (SNP) | VAF 106/1508 reads (7%) | catalogued as rs139067066; called by muse, mutect2
- CD96 | c.1148C>T p.S383F (on ENST00000283285 / NM_198196.3; = p.S367F on NM_005816.5) | Missense Mutation (SNP) | VAF 109/522 reads (21%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV51913647; called by muse, mutect2, varscan2
- CDH23 | c.8896G>A p.D2966N | Missense Mutation (SNP) | VAF 506/670 reads (76%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.517); catalogued as rs767686501; called by muse, mutect2, varscan2
- CDH9 | c.1951G>A p.D651N | Missense Mutation (SNP) | VAF 325/764 reads (43%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as rs267600596, COSV50253768; called by muse, varscan2
- CDKL5 | c.2632C>T p.P878S | Missense Mutation (SNP) | VAF 376/801 reads (47%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.005); catalogued as COSV66111570; called by muse, mutect2, varscan2
- CEACAM1 | c.1468G>A p.E490K | Missense Mutation (SNP) | VAF 258/339 reads (76%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.683); catalogued as COSV50726571; called by muse, mutect2
- CEACAM20 | c.1486G>A p.E496K | Missense Mutation (SNP) | VAF 345/453 reads (76%) | SIFT tolerated (0.14); PolyPhen benign (0.16); catalogued as COSV57602979; called by muse, mutect2, varscan2
- CEP126 | c.2794C>T p.P932S | Missense Mutation (SNP) | VAF 101/229 reads (44%) | SIFT tolerated (0.47); PolyPhen benign (0.209); catalogued as COSV54828110; called by muse, mutect2, varscan2
- CEP162 | c.268C>T p.L90F | Missense Mutation (SNP) | VAF 303/303 reads (100%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.563); catalogued as COSV57619647; called by muse, mutect2, varscan2
- CEP350 | c.89C>T p.S30L | Missense Mutation (SNP) | VAF 224/226 reads (99%) | SIFT deleterious (0.02); PolyPhen benign (0.026); catalogued as rs765028602; called by muse, mutect2, varscan2
- CFAP221 | c.913G>A p.E305K | Missense Mutation (SNP) | VAF 111/202 reads (55%) | SIFT deleterious (0.04); PolyPhen benign (0.198); catalogued as rs771543800, COSV99732217; called by muse, mutect2, varscan2
- CFAP43 | c.3373G>A p.G1125R | Missense Mutation (SNP) | VAF 87/361 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs139630636, COSV63852482; called by muse, mutect2, varscan2
- CFAP54 | c.8717T>A p.F2906Y | Missense Mutation (SNP) | VAF 191/270 reads (71%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs878862938; called by muse, mutect2, varscan2
- CFHR1 | c.128C>T p.S43F | Missense Mutation (SNP) | VAF 223/226 reads (99%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as COSV57628063; called by muse, mutect2, varscan2
- CFHR4 | c.308C>T p.S103F (on ENST00000367416 / NM_001201551.2; = p.S104F on NM_001201550.3) | Missense Mutation (SNP) | VAF 110/112 reads (98%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.852); catalogued as rs1418071957, COSV52227339; called by muse, mutect2
- CFTR | c.743G>A p.R248K | Missense Mutation (SNP) | VAF 206/913 reads (23%) | SIFT tolerated (0.36); PolyPhen benign (0.074); catalogued as rs397508792, CM972940; called by muse, varscan2
- CFTR | c.1219G>A p.E407K | Missense Mutation (SNP) | VAF 60/522 reads (11%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.007); catalogued as rs766063304; called by muse, mutect2, varscan2
- CHD5 | c.3592G>A p.E1198K | Missense Mutation (SNP) | VAF 120/752 reads (16%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.956); catalogued as COSV52406711; called by muse, varscan2
- CHRDL1 | c.1126C>T p.R376* (on ENST00000372045; = p.R382* on NM_145234.4) | Nonsense Mutation (SNP) | VAF 163/380 reads (43%) | catalogued as rs898698529, COSV54322916; called by muse, mutect2, varscan2
- CHRM3 | c.530G>A p.R177Q | Missense Mutation (SNP) | VAF 414/415 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55098538; called by muse, mutect2, varscan2
- CHRNA5 | c.187C>T p.R63C | Missense Mutation (SNP) | VAF 116/435 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs183719313, COSV55137477; called by muse, mutect2, varscan2
- CHST8 | c.775G>A p.E259K | Missense Mutation (SNP) | VAF 636/857 reads (74%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV52858516; called by muse, varscan2
- CIC | c.4736C>T p.P1579L | Missense Mutation (SNP) | VAF 160/742 reads (22%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as COSV99360434; called by muse, varscan2
- CLC | c.216G>A p.W72* | Nonsense Mutation (SNP) | VAF 474/648 reads (73%) | catalogued as COSV99695566; called by muse, mutect2, varscan2
- CLDN8 | c.568G>A p.E190K | Missense Mutation (SNP) | VAF 256/560 reads (46%) | SIFT tolerated (0.26); PolyPhen benign (0.198); catalogued as rs757114600, COSV54525792; called by muse, mutect2, varscan2
- CLEC17A | c.752G>A p.R251Q | Missense Mutation (SNP) | VAF 109/434 reads (25%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.86); catalogued as rs764808677, COSV60426617; called by muse, mutect2, varscan2
- CLIC3 | c.36G>A p.A12= | Splice Region (SNP) | VAF 212/214 reads (99%) | catalogued as rs1487684434; called by mutect2, varscan2
- CLTCL1 | c.3877C>T p.R1293C | Missense Mutation (SNP) | VAF 224/717 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); catalogued as rs781805918, COSV54238893; called by muse, varscan2
- CNKSR2 | c.727G>A p.G243R | Missense Mutation (SNP) | VAF 109/308 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.142); catalogued as COSV99669028; called by muse, varscan2
- CNTN6 | c.1798C>T p.P600S | Missense Mutation (SNP) | VAF 78/383 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1290051851, COSV63171333; called by muse, mutect2, varscan2
- CNTNAP4 | c.3014G>A p.G1005E | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.141); catalogued as COSV56674812; called by muse, varscan2
- CNTNAP5 | c.1922G>A p.R641Q | Missense Mutation (SNP) | VAF 160/496 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs371834823, COSV70498646; called by muse, mutect2, varscan2
- COG8 | c.442C>T p.R148W | Missense Mutation (SNP) | VAF 104/336 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as rs974974225; called by muse, varscan2
- COL13A1 | c.521C>T p.P174L (on ENST00000398978 / NM_001130103.2; = p.P136L on NM_080798.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 123/523 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1333975031, COSV62569109, COSV62569645; called by muse, mutect2, varscan2
- COL22A1 | c.1091G>A p.W364* | Nonsense Mutation (SNP) | VAF 155/874 reads (18%) | catalogued as rs1399651606; called by muse, varscan2
- COL4A2 | c.4291C>T p.R1431C | Missense Mutation (SNP) | VAF 88/318 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.283); catalogued as rs139124960, COSV64626395; called by muse, varscan2
- COL6A3 | c.5378G>A p.S1793N | Missense Mutation (SNP) | VAF 192/595 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.147); catalogued as rs886042944, COSV55078752; ClinVar: uncertain significance; called by muse, varscan2
- COL6A3 | c.4978C>T p.R1660C | Missense Mutation (SNP) | VAF 286/447 reads (64%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.663); catalogued as rs1553556695, COSV55092173; ClinVar: uncertain significance; called by muse, varscan2
- COL6A3 | c.4649G>A p.G1550E | Missense Mutation (SNP) | VAF 158/497 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV55078348; called by muse, mutect2, varscan2
- COL6A5 | c.6796G>A p.E2266K (on ENST00000312481; = p.E2262K on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 80/408 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.073); catalogued as rs1242504947, COSV55208131; called by muse, mutect2, varscan2
- COL6A6 | c.1923G>A p.M641I | Missense Mutation (SNP) | VAF 437/555 reads (79%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.499); catalogued as COSV62025833; called by muse, mutect2, varscan2
- COL6A6 | c.4274G>A p.G1425E | Missense Mutation (SNP) | VAF 164/520 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369345663; called by muse, mutect2, varscan2
- COLEC12 | c.480C>G p.N160K | Missense Mutation (SNP) | VAF 618/968 reads (64%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs199985975; called by muse, varscan2
- CPAMD8 | c.1702C>T p.R568C (on ENST00000651564; = p.R521C on NM_015692.5) | Missense Mutation (SNP) | VAF 292/400 reads (73%) | SIFT tolerated (0.09); PolyPhen benign (0.067); catalogued as rs762584662, COSV52230795; called by muse, mutect2, varscan2
- CPNE2 | c.1244C>T p.P415L | Missense Mutation (SNP) | VAF 103/345 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs1283939208; called by muse, mutect2, varscan2
- CPT1C | c.1109C>T p.S370L | Missense Mutation (SNP) | VAF 167/657 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.566); catalogued as rs376513063; called by muse, mutect2, varscan2
- CPVL | c.95C>T p.S32F | Missense Mutation (SNP) | VAF 209/478 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs866569810; called by muse, mutect2, varscan2
- CR1 | c.4033G>A p.E1345K | Missense Mutation (SNP) | VAF 269/270 reads (100%) | SIFT tolerated (0.14); PolyPhen benign (0.375); catalogued as COSV100887649; called by muse, mutect2, varscan2
- CRB1 | c.1276G>A p.D426N | Missense Mutation (SNP) | VAF 251/412 reads (61%) | SIFT tolerated (0.3); PolyPhen benign (0.432); catalogued as COSV66334283; called by muse, mutect2, varscan2
- CRB2 | c.784G>A p.E262K | Missense Mutation (SNP) | VAF 170/574 reads (30%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.46); catalogued as rs750735887; called by muse, mutect2, varscan2
- CREB3L3 | c.553C>T p.L185F | Missense Mutation (SNP) | VAF 96/502 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs776820034, COSV50189294; called by muse, mutect2, varscan2
- CROCC | c.3797C>T p.T1266I | Missense Mutation (SNP) | VAF 610/817 reads (75%) | SIFT deleterious (0); PolyPhen benign (0.052); catalogued as COSV65010966; called by muse, mutect2, varscan2
- CSF1R | c.854G>A p.G285D | Missense Mutation (SNP) | VAF 320/448 reads (71%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); catalogued as rs1221149937; called by muse, mutect2, varscan2
- CSMD1 | c.9332G>A p.G3111E (on ENST00000520002; = p.G3110E on NM_033225.6) | Missense Mutation (SNP) | VAF 136/533 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59338867; called by muse, mutect2, varscan2
- CSMD1 | c.6062C>T p.S2021F (on ENST00000520002; = p.S2020F on NM_033225.6) | Missense Mutation (SNP) | VAF 355/484 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1456963597, COSV59327200; called by muse, varscan2
- CSMD1 | c.3229C>T p.R1077C (on ENST00000520002; = p.R1076C on NM_033225.6) | Missense Mutation (SNP) | VAF 146/713 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs867742507, COSV59279573, COSV59288383; called by muse, varscan2
- CSMD2 | c.4678G>A p.D1560N | Missense Mutation (SNP) | VAF 128/557 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as COSV99589625; called by muse, mutect2, varscan2
- CSPG4 | c.3382C>T p.R1128C | Missense Mutation (SNP) | VAF 171/561 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); catalogued as rs765420925, COSV57893485; called by muse, mutect2, varscan2
- CTNNA2 | c.1912G>A p.D638N | Missense Mutation (SNP) | VAF 236/428 reads (55%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.752); catalogued as rs1444733248; called by muse, varscan2
- CUZD1 | c.782C>T p.S261F | Missense Mutation (SNP) | VAF 212/320 reads (66%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.916); catalogued as rs1321007301; called by muse, mutect2, varscan2
- CYP2C19 | c.158C>T p.S53F | Missense Mutation (SNP) | VAF 65/234 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.567); catalogued as COSV64907584; called by muse, varscan2
- CYP2C19 | c.820G>A p.E274K | Missense Mutation (SNP) | VAF 75/273 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.345); catalogued as COSV64909429; called by muse, mutect2, varscan2
- CYP2C9 | c.973G>A p.E325K | Missense Mutation (SNP) | VAF 75/319 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.048); catalogued as rs780145404; called by muse, mutect2, varscan2
- CYP2D7 | c.1489C>T p.R497C | Missense Mutation (SNP) | VAF 666/1180 reads (56%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.571); catalogued as rs3171710, COSV100809518; called by muse, mutect2, varscan2
- CYP2J2 | c.524G>A p.G175E | Missense Mutation (SNP) | VAF 77/354 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1424304237; called by muse, varscan2
- CYP4F11 | c.222G>A p.M74I | Missense Mutation (SNP) | VAF 298/426 reads (70%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as rs867623911; called by muse, mutect2
- CYP4F22 | c.446G>A p.G149D | Missense Mutation (SNP) | VAF 375/522 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs751335732, COSV54107918; called by muse, mutect2, varscan2
- CYP7B1 | c.961G>A p.E321K | Missense Mutation (SNP) | VAF 126/790 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs866340497, COSV59582915; called by muse, mutect2, varscan2
- CYSLTR1 | c.444G>A p.W148* | Nonsense Mutation (SNP) | VAF 310/642 reads (48%) | catalogued as rs866204187; called by muse, varscan2
- CYTIP | c.370G>A p.G124S | Missense Mutation (SNP) | VAF 109/371 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51633051; called by muse, mutect2, varscan2
- DAB1 | c.1384C>T p.R462C (on ENST00000371231; = p.R429C on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 143/779 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs1325593862; called by muse, mutect2, varscan2
- DAB2 | c.1213G>A p.G405R | Missense Mutation (SNP) | VAF 356/954 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.938); catalogued as rs758202197, COSV100297923; called by muse, mutect2, varscan2
- DCC | c.1753C>G p.L585V | Missense Mutation (SNP) | VAF 385/601 reads (64%) | SIFT tolerated (0.32); PolyPhen benign (0.129); catalogued as COSV100498788; called by muse, mutect2, varscan2
- DCDC1 | c.719G>A p.G240E | Missense Mutation (SNP) | VAF 95/304 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.799); catalogued as COSV100664171, COSV60848936; called by muse, mutect2, varscan2
- DCUN1D3 | c.377G>C p.R126P | Missense Mutation (SNP) | VAF 152/452 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.307); catalogued as rs759576387, COSV100176743, COSV60952743; called by muse, mutect2, varscan2
- DDO | c.494G>A p.R165Q (on ENST00000368924 / NM_001368172.1; = p.R106Q on NM_004032.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 366/368 reads (99%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.555); catalogued as rs779200242, COSV64470397; called by muse, mutect2, varscan2
- DEFB116 | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 102/478 reads (21%) | SIFT tolerated (0.65); PolyPhen benign (0.185); catalogued as COSV101269208; called by muse, mutect2, varscan2
- DHRS7C | c.871C>T p.P291S (on ENST00000330255 / NM_001220493.2; = p.P290S on NM_001105571.3) | Missense Mutation (SNP) | VAF 756/758 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs957007375; called by muse, mutect2, varscan2
- DKK2 | c.497G>A p.G166E | Missense Mutation (SNP) | VAF 225/225 reads (100%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs770400633, COSV53394433; called by muse, mutect2, varscan2
- DLEC1 | c.4315G>A p.E1439K | Missense Mutation (SNP) | VAF 98/443 reads (22%) | SIFT tolerated (0.62); PolyPhen benign (0.225); catalogued as COSV57295156; called by muse, mutect2, varscan2
- DLL1 | c.556G>A p.E186K | Missense Mutation (SNP) | VAF 806/808 reads (100%) | SIFT tolerated (0.06); PolyPhen benign (0.438); catalogued as rs1243238981; called by muse, varscan2
- DMD | c.3152G>A p.R1051Q | Missense Mutation (SNP) | VAF 175/353 reads (50%) | SIFT tolerated (0.49); PolyPhen benign (0.01); catalogued as rs761715369, COSV63739030; called by muse, mutect2, varscan2
- DMGDH | c.2267G>A p.G756E | Missense Mutation (SNP) | VAF 240/343 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54861171; called by muse, mutect2, varscan2
- DNAH11 | c.511C>A p.L171I | Missense Mutation (SNP) | VAF 100/232 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.072); catalogued as COSV60961903; called by muse, mutect2, varscan2
- DNAH12 | c.3383C>T p.T1128M (on ENST00000351747; = p.T1151M on NM_001366028.2) | Missense Mutation (SNP) | VAF 71/387 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.183); catalogued as rs372611509; called by muse, mutect2, varscan2
- DNAH17 | c.6691G>A p.E2231K | Missense Mutation (SNP) | VAF 122/822 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778357087; called by muse, varscan2
- DNAH5 | c.13775G>A p.R4592Q | Missense Mutation (SNP) | VAF 275/641 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs367709427, COSV54253927; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH5 | c.12461C>T p.P4154L | Missense Mutation (SNP) | VAF 207/508 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs868750896; called by muse, mutect2, varscan2
- DNAH5 | c.771G>A p.M257I | Missense Mutation (SNP) | VAF 309/546 reads (57%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV54223750; called by muse, mutect2, varscan2
- DNAH6 | c.9415C>T p.L3139F | Missense Mutation (SNP) | VAF 275/471 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99404509; called by muse, mutect2, varscan2
- DNAH8 | c.2642C>T p.S881F | Missense Mutation (SNP) | VAF 158/498 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.092); catalogued as rs553578959, COSV59469912; called by muse, varscan2
- DNAH8 | c.10282C>T p.L3428F | Missense Mutation (SNP) | VAF 152/542 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); catalogued as rs1446285473; called by muse, mutect2, varscan2
- DNAH9 | c.12074A>G p.N4025S | Missense Mutation (SNP) | VAF 403/411 reads (98%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.712); catalogued as rs772352224; called by muse, mutect2, varscan2
- DNAJC18 | c.680C>T p.S227F | Missense Mutation (SNP) | VAF 49/242 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs1393218973; called by muse, mutect2, varscan2
- DOCK3 | c.5904G>A p.M1968I | Missense Mutation (SNP) | VAF 228/1164 reads (20%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as rs1247576945; called by muse, varscan2
- DOCK6 | c.1835C>T p.S612F | Missense Mutation (SNP) | VAF 110/476 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.866); catalogued as rs368164863; called by muse, varscan2
- DOCK7 | c.3530C>T p.S1177F (on ENST00000635253 / NM_001367561.1; = p.S1146F on NM_033407.3) | Missense Mutation (SNP) | VAF 109/620 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1438314720; called by muse, mutect2, varscan2
- DOCK7 | c.2677C>T p.R893C | Missense Mutation (SNP) | VAF 453/616 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs374515298, COSV52003536; called by muse, mutect2, varscan2
- DOK6 | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 216/739 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV101234532; called by muse, varscan2
- DPYD | c.2798G>A p.G933E | Missense Mutation (SNP) | VAF 391/493 reads (79%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV100928980; called by muse, mutect2, varscan2
- DSC3 | c.607C>T p.R203C | Missense Mutation (SNP) | VAF 176/571 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs757290041, COSV64571675; called by muse, mutect2, varscan2
- DSCAML1 | c.2969C>T p.S990F (on ENST00000321322; = p.S930F on NM_020693.4) | Missense Mutation (SNP) | VAF 101/215 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as rs1465069433, COSV58394347; called by muse, mutect2, varscan2
- DSPP | c.997C>T p.P333S | Missense Mutation (SNP) | VAF 251/350 reads (72%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0.006); catalogued as COSV104390375; called by muse, mutect2, varscan2
- DYDC1 | c.445C>T p.R149C | Missense Mutation (SNP) | VAF 285/374 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs368866721; called by muse, mutect2, varscan2
- DYM | c.1867C>T p.P623S | Missense Mutation (SNP) | VAF 146/446 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53987059; called by muse, varscan2
- EDRF1 | c.692C>T p.S231L | Missense Mutation (SNP) | VAF 303/441 reads (69%) | SIFT tolerated (0.2); PolyPhen benign (0.053); catalogued as rs745329281; called by muse, varscan2
- EEF2K | c.986C>T p.S329L | Missense Mutation (SNP) | VAF 316/500 reads (63%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.503); catalogued as rs780264247; called by muse, varscan2
- EGFLAM | c.239C>T p.S80F | Missense Mutation (SNP) | VAF 396/731 reads (54%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.003); catalogued as COSV59320213; called by muse, mutect2, varscan2
- EGFLAM | c.1577G>A p.G526E | Missense Mutation (SNP) | VAF 462/892 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100380645; called by muse, varscan2
- ELAVL4 | c.732C>T p.F244= | Splice Region (SNP) | VAF 69/472 reads (15%) | catalogued as COSV63918742; called by muse, varscan2
- EML6 | c.411G>A p.W137* | Nonsense Mutation (SNP) | VAF 233/444 reads (52%) | catalogued as rs1553385573; called by muse, mutect2, varscan2
- ENPP4 | c.873G>A p.M291I | Missense Mutation (SNP) | VAF 53/461 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.097); catalogued as rs775632459, COSV58090385; called by muse, mutect2, varscan2
- EPHB3 | c.221C>T p.P74L | Missense Mutation (SNP) | VAF 102/558 reads (18%) | SIFT tolerated (0.13); PolyPhen probably damaging (1); catalogued as COSV57807532; called by muse, mutect2, varscan2
- ERC2 | c.1811G>A p.R604Q | Missense Mutation (SNP) | VAF 92/542 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as rs751475951, COSV55609509; called by muse, mutect2, varscan2
- ERC2 | c.962G>A p.S321N | Missense Mutation (SNP) | VAF 173/759 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.058); catalogued as rs759704719, COSV55650368; called by muse, varscan2
- ERICH3 | c.3026C>T p.S1009L | Missense Mutation (SNP) | VAF 582/766 reads (76%) | SIFT tolerated (0.86); PolyPhen benign (0.007); catalogued as rs1365373663, COSV58605892; called by muse, varscan2
- ERICH3 | c.317G>A p.G106E | Missense Mutation (SNP) | VAF 98/449 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs745779160; called by muse, varscan2
- ESX1 | c.1000C>T p.P334S | Missense Mutation (SNP) | VAF 550/1332 reads (41%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.125); catalogued as rs1459875754; called by muse, varscan2
- EYS | c.7781G>A p.G2594E | Missense Mutation (SNP) | VAF 119/660 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.605); catalogued as COSV65475489; called by muse, mutect2, varscan2
- F13A1 | c.449C>T p.S150F | Missense Mutation (SNP) | VAF 662/1052 reads (63%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.97); catalogued as COSV53562917; called by muse, varscan2
- FAIM2 | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 399/622 reads (64%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs267603498, COSV57739214; called by muse, mutect2, varscan2
- FAM131B | c.-56G>A | Splice Region (SNP) | VAF 259/653 reads (40%) | catalogued as rs1445716572, COSV101281761; called by muse, varscan2
- FAM131C | c.613G>A p.D205N | Missense Mutation (SNP) | VAF 88/860 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.711); catalogued as rs1370207463; called by muse, mutect2, varscan2
- FAM135B | c.4063G>A p.E1355K | Missense Mutation (SNP) | VAF 128/682 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.054); catalogued as COSV99422191; called by muse, varscan2
- FAM171A1 | c.1217G>A p.G406D | Missense Mutation (SNP) | VAF 150/489 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.966); catalogued as rs1160793865; called by muse, varscan2
- FAM3D | c.373G>A p.D125N | Missense Mutation (SNP) | VAF 568/713 reads (80%) | SIFT deleterious (0.02); PolyPhen benign (0.3); catalogued as COSV100716744; called by muse, varscan2
- FAM71B | c.400G>A p.D134N | Missense Mutation (SNP) | VAF 63/277 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0.099); catalogued as rs543304286, COSV57229990; called by muse, mutect2, varscan2
- FAM91A1 | c.947C>T p.S316F | Missense Mutation (SNP) | VAF 60/382 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV58235410; called by muse, varscan2
- FATE1 | c.121G>A p.G41R | Missense Mutation (SNP) | VAF 116/226 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.147); catalogued as COSV64848920, COSV64849094; called by muse, varscan2
- FBXO40 | c.2107C>T p.P703S | Missense Mutation (SNP) | VAF 91/425 reads (21%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.007); catalogued as rs147555575; called by muse, mutect2, varscan2
- FCRL4 | c.1375G>A p.G459R | Missense Mutation (SNP) | VAF 382/382 reads (100%) | SIFT tolerated (0.83); PolyPhen benign (0.005); catalogued as COSV54860005, COSV99620480; called by muse, varscan2
- FCRL4 | c.215G>A p.G72E | Missense Mutation (SNP) | VAF 455/458 reads (99%) | SIFT tolerated (0.24); PolyPhen benign (0.261); catalogued as rs868440077; called by muse, mutect2, varscan2
- FERMT1 | c.410C>T p.S137F | Missense Mutation (SNP) | VAF 70/322 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54090904; called by muse, mutect2, varscan2
- FGF18 | c.178C>T p.R60W | Missense Mutation (SNP) | VAF 140/566 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); catalogued as rs756441926, COSV51127441; called by muse, mutect2, varscan2
- FHAD1 | c.2413G>A p.E805K | Missense Mutation (SNP) | VAF 448/616 reads (73%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.745); catalogued as rs1044521497, COSV100119642; called by muse, varscan2
- FILIP1 | c.1981G>A p.D661N | Missense Mutation (SNP) | VAF 202/376 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV52743247; called by muse, varscan2
- FIP1L1 | c.1580G>A p.R527Q | Missense Mutation (SNP) | VAF 465/466 reads (100%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as rs760139823; called by muse, varscan2
- FLG2 | c.6455G>A p.G2152E | Missense Mutation (SNP) | VAF 436/438 reads (100%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.996); catalogued as rs138607426, COSV66171624; called by muse, varscan2
- FLG2 | c.4840C>T p.H1614Y | Missense Mutation (SNP) | VAF 445/448 reads (99%) | SIFT deleterious (0.04); PolyPhen benign (0.042); catalogued as COSV66173685; called by muse, mutect2, varscan2
- FLNC | c.2317G>A p.G773R | Missense Mutation (SNP) | VAF 485/1544 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1322212555; ClinVar: uncertain significance; called by muse, varscan2
- FLT1 | c.1496G>A p.G499E | Missense Mutation (SNP) | VAF 237/372 reads (64%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.742); catalogued as COSV56745835; called by muse, mutect2, varscan2
- FLT3 | c.2276C>T p.S759L | Missense Mutation (SNP) | VAF 94/335 reads (28%) | SIFT tolerated (0.33); PolyPhen benign (0.01); catalogued as COSV54060926; called by muse, mutect2, varscan2
- FSHB | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 298/456 reads (65%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.847); catalogued as COSV54221544; called by muse, varscan2
- FSHR | c.373C>T p.L125= | Splice Region (SNP) | VAF 159/450 reads (35%) | catalogued as COSV58617246; called by muse, mutect2, varscan2
- FTCD | c.35C>T p.S12L | Missense Mutation (SNP) | VAF 168/855 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201753824, COSV52426509; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FUT7 | c.59G>A p.G20E | Missense Mutation (SNP) | VAF 566/567 reads (100%) | SIFT tolerated (0.15); PolyPhen benign (0.309); catalogued as COSV55800479; called by muse, mutect2, varscan2
- FUT9 | c.20G>A p.G7E | Missense Mutation (SNP) | VAF 171/318 reads (54%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.755); catalogued as rs146406553, COSV56142363; called by muse, mutect2, varscan2
- FYB2 | c.1155G>A p.M385I | Missense Mutation (SNP) | VAF 70/397 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as rs759460902, COSV58586953; called by muse, mutect2, varscan2
- GABRA2 | c.1076C>T p.S359F | Missense Mutation (SNP) | VAF 272/272 reads (100%) | SIFT tolerated (0.06); PolyPhen benign (0.387); catalogued as COSV62916658; called by muse, varscan2
- GABRB3 | c.1340C>T p.A447V | Missense Mutation (SNP) | VAF 218/465 reads (47%) | SIFT tolerated (0.64); PolyPhen benign (0.009); catalogued as COSV54655540; called by muse, mutect2, varscan2
- GABRG1 | c.98G>A p.G33E | Missense Mutation (SNP) | VAF 186/187 reads (99%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.994); catalogued as COSV54950313; called by muse, mutect2, varscan2
- GAL3ST1 | c.604C>T p.R202C | Missense Mutation (SNP) | VAF 425/1104 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as rs764727999, COSV58892475; called by muse, mutect2, varscan2
- GALNTL6 | c.1042-1G>A p.X348_splice | Splice Site (SNP) | VAF 232/235 reads (99%) | catalogued as COSV72493747; called by muse, mutect2, varscan2
- GATA2 | c.1402G>A p.G468S | Missense Mutation (SNP) | VAF 189/1016 reads (19%) | SIFT tolerated (0.41); PolyPhen benign (0.086); catalogued as rs777726701; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GBP6 | c.1804G>A p.D602N | Missense Mutation (SNP) | VAF 386/518 reads (75%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as rs142400726; called by muse, mutect2, varscan2
- GET1-SH3BGR | c.388G>A p.D130N | Missense Mutation (SNP) | VAF 98/463 reads (21%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.984); catalogued as rs1394415998, COSV100374611; called by muse, mutect2, varscan2
- GFRAL | c.293G>A p.G98E | Missense Mutation (SNP) | VAF 312/376 reads (83%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.721); catalogued as COSV61229115; called by muse, varscan2
- GIMAP2 | c.533G>A p.R178Q | Missense Mutation (SNP) | VAF 399/1010 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs141987826; called by muse, mutect2, varscan2
- GIMAP4 | c.232G>A p.E78K | Missense Mutation (SNP) | VAF 293/701 reads (42%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.601); catalogued as rs1352695671, COSV55432152; called by muse, mutect2, varscan2
- GIMAP6 | c.832G>A p.E278K | Missense Mutation (SNP) | VAF 201/739 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.042); catalogued as rs865805939, COSV61032437; called by muse, mutect2, varscan2
- GJB4 | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 414/1111 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.133); catalogued as rs773421859, COSV58357048; called by muse, varscan2
- GMNC | c.316G>A p.E106K | Missense Mutation (SNP) | VAF 253/606 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV71249030; called by muse, mutect2, varscan2
- GOLGA6L7 | c.194G>A p.R65Q | Missense Mutation (SNP) | VAF 177/591 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.38); catalogued as rs763513868, COSV101629716; called by muse, mutect2, varscan2
- GPC4 | c.356C>T p.S119F | Missense Mutation (SNP) | VAF 196/502 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63698750; called by muse, varscan2
- GPR139 | c.509G>A p.W170* | Nonsense Mutation (SNP) | VAF 131/443 reads (30%) | catalogued as rs868806533, COSV100429930; called by muse, mutect2, varscan2
- GPR158 | c.2332G>A p.D778N | Missense Mutation (SNP) | VAF 196/656 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.098); catalogued as rs747693904, COSV66266831; called by muse, varscan2
- GPR61 | c.976G>A p.V326I | Missense Mutation (SNP) | VAF 167/792 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as rs565432681; called by muse, mutect2, varscan2
- GRAMD2A | c.185G>A p.R62Q | Missense Mutation (SNP) | VAF 130/378 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as rs999473779; called by muse, varscan2
- GREB1L | c.274G>A p.D92N | Missense Mutation (SNP) | VAF 266/975 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.324); catalogued as rs778569433; called by muse, varscan2
- GREB1L | c.2392G>A p.E798K | Missense Mutation (SNP) | VAF 38/718 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.4); catalogued as rs868440722; called by muse, mutect2
- GRIA1 | c.1883C>T p.S628F | Missense Mutation (SNP) | VAF 246/369 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53624114; called by muse, mutect2, varscan2
- GRIN2B | c.3562G>A p.G1188S | Missense Mutation (SNP) | VAF 185/607 reads (30%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.006); catalogued as rs367543149, COSV101662898; ClinVar: not provided; called by muse, mutect2
- GRIN2B | c.799G>A p.D267N | Missense Mutation (SNP) | VAF 140/469 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.673); catalogued as COSV101663149; called by muse, mutect2, varscan2
- GRIPAP1 | c.697G>A p.E233K | Missense Mutation (SNP) | VAF 189/436 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.373); catalogued as COSV64552540; called by muse, mutect2, varscan2
- GRM8 | c.386C>T p.S129L | Missense Mutation (SNP) | VAF 779/1207 reads (65%) | SIFT deleterious (0.01); PolyPhen benign (0.067); catalogued as rs143468706; called by muse, mutect2, varscan2
- GSG1L | c.397+1G>A p.X133_splice | Splice Site (SNP) | VAF 264/403 reads (66%) | catalogued as COSV66593464; called by muse, varscan2
- GSTA1 | c.319C>T p.L107F | Missense Mutation (SNP) | VAF 156/510 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as rs1472380126, COSV58015073; called by muse, mutect2, varscan2
- GTF2H3 | c.203G>A p.R68Q | Missense Mutation (SNP) | VAF 16/239 reads (7%) | SIFT tolerated (0.66); PolyPhen benign (0.33); catalogued as rs1335730367, COSV57459442; called by muse, mutect2
- GUCY2D | c.1264C>T p.P422S | Missense Mutation (SNP) | VAF 915/916 reads (100%) | SIFT tolerated (0.76); PolyPhen benign (0.017); catalogued as COSV54695107; called by muse, mutect2, varscan2
- HCN2 | c.2477C>T p.S826L | Missense Mutation (SNP) | VAF 114/115 reads (99%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.184); catalogued as rs1191857264; called by muse, varscan2
- HDGFL1 | c.484G>A p.E162K | Missense Mutation (SNP) | VAF 892/1364 reads (65%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as rs765436695; called by muse, varscan2
- HFM1 | c.802C>T p.P268S | Missense Mutation (SNP) | VAF 233/331 reads (70%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.95); catalogued as rs199692136; called by muse, mutect2, varscan2
- HHIP | c.1291G>A p.D431N | Missense Mutation (SNP) | VAF 368/370 reads (99%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs369873424; called by muse, varscan2
- HIF3A | c.1573C>T p.R525W (on ENST00000377670 / NM_152795.4; = p.R456W on NM_022462.4) | Missense Mutation (SNP) | VAF 254/1040 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs148799051; called by muse, varscan2
- HIPK1 | c.577T>A p.L193M | Missense Mutation (SNP) | VAF 123/666 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65782991; called by muse, mutect2, varscan2
- HMGCLL1 | c.527C>T p.S176F | Missense Mutation (SNP) | VAF 108/574 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51451651; called by muse, mutect2, varscan2
- HNF4A | c.1414G>A p.E472K | Missense Mutation (SNP) | VAF 241/514 reads (47%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.444); catalogued as rs748452860, COSV57382487; called by muse, varscan2
- HNRNPR | c.55A>G p.M19V | Missense Mutation (SNP) | VAF 144/664 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.014); catalogued as rs758506054; called by muse, mutect2, varscan2
- HS3ST4 | c.1177G>A p.G393R | Missense Mutation (SNP) | VAF 275/456 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs367931100, COSV100499854; called by muse, mutect2, varscan2
- HSD17B2 | c.374G>A p.R125Q | Missense Mutation (SNP) | VAF 91/283 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.392); catalogued as rs779171937, COSV52274204; called by muse, varscan2
- HTR1A | c.640C>T p.L214F | Missense Mutation (SNP) | VAF 125/574 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1403228466, COSV60501438, COSV60502125; called by muse, varscan2
- HTR3A | c.1049G>A p.R350K | Missense Mutation (SNP) | VAF 146/310 reads (47%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as rs867161218, COSV100248571; called by muse, mutect2, varscan2
- HUS1B | c.175C>T p.R59W | Missense Mutation (SNP) | VAF 180/1076 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.767); catalogued as rs867882133; called by muse, varscan2
- HYDIN | c.6394G>A p.E2132K | Missense Mutation (SNP) | VAF 136/221 reads (62%) | SIFT tolerated (0.12); PolyPhen benign (0.359); catalogued as rs373417090; called by muse, mutect2, varscan2
- IFIT2 | c.1379G>A p.G460E | Missense Mutation (SNP) | VAF 247/354 reads (70%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs1224127615; called by muse, varscan2
- IFNG | c.455G>A p.R152Q | Missense Mutation (SNP) | VAF 272/440 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs377736305; called by muse, varscan2
- IFT140 | c.3568G>A p.E1190K | Missense Mutation (SNP) | VAF 350/511 reads (68%) | SIFT tolerated (0.22); PolyPhen benign (0.021); catalogued as rs752576154; called by muse, mutect2, varscan2
- IGKV1-5 | c.262G>A p.G88R | Missense Mutation (SNP) | VAF 481/851 reads (57%) | SIFT deleterious (0.05); PolyPhen benign (0.37); catalogued as rs773635617; called by muse, varscan2
- IGKV4-1 | c.100T>C p.S34P | Missense Mutation (SNP) | VAF 282/503 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.28); catalogued as rs72847567; called by muse, mutect2, varscan2
- IL1RAPL1 | c.750T>G p.S250R | Missense Mutation (SNP) | VAF 158/354 reads (45%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs1402973430; called by muse, varscan2
- IL20RA | c.1286G>A p.G429E | Missense Mutation (SNP) | VAF 322/569 reads (57%) | SIFT tolerated (0.15); PolyPhen benign (0.092); catalogued as rs138424318; called by muse, mutect2, varscan2
- IL27 | c.53C>T p.P18L | Missense Mutation (SNP) | VAF 132/445 reads (30%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.04); catalogued as rs1246707653; called by muse, varscan2
- IL36B | c.413C>T p.S138F | Missense Mutation (SNP) | VAF 74/285 reads (26%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV52084330; called by muse, varscan2
- IL37 | c.64C>T p.P22S | Missense Mutation (SNP) | VAF 105/365 reads (29%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as rs1489179993; called by muse, mutect2, varscan2
- IL7R | c.1268C>T p.S423F | Missense Mutation (SNP) | VAF 564/1028 reads (55%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.747); catalogued as COSV57406297, COSV57407283; called by muse, varscan2
- INPP5F | c.1495C>T p.R499C | Missense Mutation (SNP) | VAF 304/451 reads (67%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as rs775757691, COSV62820590, COSV62821584; called by muse, varscan2
- INSYN2A | c.949G>A p.E317K | Missense Mutation (SNP) | VAF 326/742 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.371); catalogued as rs143223796; called by muse, varscan2
- IQCJ | c.374G>A p.R125K | Missense Mutation (SNP) | VAF 513/656 reads (78%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.003); catalogued as rs1436503993; called by muse, mutect2, varscan2
- IQCJ-SCHIP1 | c.275C>T p.S92F | Missense Mutation (SNP) | VAF 122/724 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs758844693; called by muse, mutect2, varscan2
- IQSEC3 | c.3073G>A p.E1025K (on ENST00000538872 / NM_001170738.2; = p.E722K on NM_015232.1) | Missense Mutation (SNP) | VAF 179/526 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs868968040, COSV58285092; called by muse, mutect2
- IRAK1 | c.970C>T p.R324W | Missense Mutation (SNP) | VAF 101/596 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1557129491; called by muse, mutect2, varscan2
- ISY1-RAB43 | c.781A>G p.M261V | Missense Mutation (SNP) | VAF 457/594 reads (77%) | SIFT tolerated (0.13); PolyPhen benign (0.219); catalogued as rs749056720, COSV99860806; called by muse, varscan2
- ITGA10 | c.290G>A p.G97E | Missense Mutation (SNP) | VAF 96/271 reads (35%) | SIFT tolerated (0.36); PolyPhen benign (0.358); catalogued as COSV65196112; called by muse, varscan2
- ITGA2B | c.1883G>A p.R628Q | Missense Mutation (SNP) | VAF 294/610 reads (48%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.993); catalogued as rs1210956482, COSV52232893; called by muse, mutect2, varscan2
- ITGAL | c.2224G>A p.D742N | Missense Mutation (SNP) | VAF 156/302 reads (52%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as COSV63320430; called by muse, mutect2, varscan2
- ITIH5 | c.1416C>T p.I472= | Splice Region (SNP) | VAF 159/239 reads (67%) | catalogued as rs910753360, COSV99906272; called by muse, mutect2, varscan2
- ITK | c.691C>T p.P231S | Missense Mutation (SNP) | VAF 164/254 reads (65%) | SIFT tolerated (0.81); PolyPhen benign (0.003); catalogued as COSV70065191; called by muse, varscan2
- ITPRIP | c.1015C>T p.R339C | Missense Mutation (SNP) | VAF 408/564 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs780957842, COSV53393198; called by muse, varscan2
- ITSN2 | c.601G>C p.G201R | Missense Mutation (SNP) | VAF 180/547 reads (33%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.958); catalogued as rs754963285; called by muse, mutect2, varscan2
- JADE2 | c.1000C>T p.H334Y | Missense Mutation (SNP) | VAF 176/247 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99253725; called by muse, mutect2, varscan2
- KCNA3 | c.784G>A p.E262K | Missense Mutation (SNP) | VAF 171/769 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.022); catalogued as rs1238509684; called by muse, mutect2, varscan2
- KCNB2 | c.1049C>T p.S350F | Missense Mutation (SNP) | VAF 206/1024 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV73050367; called by muse, varscan2
- KCNG4 | c.1054C>T p.R352C | Missense Mutation (SNP) | VAF 287/451 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759093264, COSV57584090; called by muse, varscan2
- KCNH5 | c.92G>A p.G31E | Missense Mutation (SNP) | VAF 190/361 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100527372; called by muse, mutect2, varscan2
- KCNH7 | c.2702G>A p.G901E | Missense Mutation (SNP) | VAF 70/264 reads (27%) | SIFT tolerated (0.36); PolyPhen benign (0.013); catalogued as COSV59804554; called by muse, varscan2
- KCNN1 | c.116G>A p.S39N | Missense Mutation (SNP) | VAF 276/1098 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.125); catalogued as rs749961468; called by muse, varscan2
- KCNQ3 | c.1225C>T p.P409S | Missense Mutation (SNP) | VAF 84/490 reads (17%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); catalogued as COSV66475740; called by muse, mutect2, varscan2
- KDM6A | c.997C>T p.Q333* | Nonsense Mutation (SNP) | VAF 119/572 reads (21%) | catalogued as COSV65038913, COSV65040651; called by muse, mutect2, varscan2
- KIF2B | c.394G>A p.D132N | Missense Mutation (SNP) | VAF 355/753 reads (47%) | SIFT tolerated (0.49); PolyPhen benign (0.031); catalogued as COSV52136156; called by muse, mutect2, varscan2
- KIF6 | c.399+1G>A p.X133_splice | Splice Site (SNP) | VAF 282/438 reads (64%) | catalogued as rs771821721, COSV99757212; called by muse, varscan2
- KIF7 | c.1022A>G p.N341S | Missense Mutation (SNP) | VAF 247/728 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.478); catalogued as rs757699508; called by muse, varscan2
- KIR2DL3 | c.328C>T p.Q110* | Nonsense Mutation (SNP) | VAF 208/604 reads (34%) | catalogued as rs754862541, COSV60897196; called by muse, varscan2
- KLF10 | c.469C>T p.R157C | Missense Mutation (SNP) | VAF 168/916 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); catalogued as COSV53436220; called by muse, mutect2, varscan2
- KLHL3 | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 84/426 reads (20%) | SIFT tolerated (0.49); PolyPhen benign (0.021); catalogued as rs976865705; called by muse, varscan2
- KLK1 | c.700C>T p.P234S | Missense Mutation (SNP) | VAF 172/753 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV100032766; called by muse, varscan2
- KLK2 | c.712G>A p.E238K | Missense Mutation (SNP) | VAF 298/623 reads (48%) | SIFT tolerated (0.58); PolyPhen benign (0.013); catalogued as COSV100320049; called by muse, mutect2, varscan2
- KLRF1 | c.601G>A p.G201R | Missense Mutation (SNP) | VAF 62/185 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54380769; called by muse, varscan2
- KMT2D | c.13363C>T p.R4455C | Missense Mutation (SNP) | VAF 177/627 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs530054198; called by muse, mutect2, varscan2
- KMT5C | c.283C>T p.R95C | Missense Mutation (SNP) | VAF 82/375 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as rs764360208, COSV55318969; called by muse, varscan2
- KRBA1 | c.2755C>T p.P919S | Missense Mutation (SNP) | VAF 548/1252 reads (44%) | SIFT tolerated (0.41); PolyPhen benign (0.197); catalogued as rs761843078; called by muse, varscan2
- KRT27 | c.277G>A p.D93N | Missense Mutation (SNP) | VAF 270/586 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.751); catalogued as rs762368035; called by muse, varscan2
- KRT32 | c.1009G>A p.E337K | Missense Mutation (SNP) | VAF 428/428 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99862956; called by muse, varscan2
- KSR1 | c.571G>A p.E191K (on ENST00000644974 / NM_001367810.1; = p.E54K on NM_014238.2) | Missense Mutation (SNP) | VAF 922/923 reads (100%) | SIFT tolerated (0.24); PolyPhen benign (0.272); catalogued as rs764032318; called by muse, mutect2, varscan2
- KYNU | c.925G>A p.E309K | Missense Mutation (SNP) | VAF 155/232 reads (67%) | SIFT tolerated (0.96); PolyPhen benign (0.005); catalogued as COSV51585309; called by muse, mutect2, varscan2
- LAMA1 | c.748G>A p.D250N | Missense Mutation (SNP) | VAF 150/572 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101057260; called by muse, mutect2, varscan2
- LAMA2 | c.994G>A p.A332T | Missense Mutation (SNP) | VAF 372/374 reads (99%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV70337829, COSV70345955; called by muse, mutect2, varscan2
- LAMA2 | c.4496G>A p.R1499Q | Missense Mutation (SNP) | VAF 307/307 reads (100%) | SIFT tolerated (0.56); PolyPhen benign (0.325); catalogued as rs375100782; called by muse, varscan2
- LCORL | c.4945C>T p.P1649S | Missense Mutation (SNP) | VAF 104/377 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.048); catalogued as rs1404782247; called by muse, varscan2
- LEPR | c.2004G>A p.M668I | Missense Mutation (SNP) | VAF 310/383 reads (81%) | SIFT tolerated (0.06); PolyPhen benign (0.164); catalogued as COSV60759035; called by muse, mutect2, varscan2
- LGR6 | c.1442C>T p.P481L (on ENST00000367278 / NM_001017403.1; = p.P429L on NM_021636.3) | Missense Mutation (SNP) | VAF 416/416 reads (100%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as rs1373153177; called by muse, varscan2
- LHCGR | c.415C>T p.P139S | Missense Mutation (SNP) | VAF 163/506 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54296277; called by muse, mutect2, varscan2
- LIFR | c.2752C>T p.P918S | Missense Mutation (SNP) | VAF 348/651 reads (53%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.834); catalogued as COSV54693785; called by muse, mutect2, varscan2
- LILRA4 | c.1382G>A p.G461E | Missense Mutation (SNP) | VAF 620/856 reads (72%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV52493768; called by muse, varscan2
- LILRB5 | c.1567G>A p.E523K (on ENST00000449561 / NM_001081442.3; = p.E522K on NM_006840.5) | Missense Mutation (SNP) | VAF 190/834 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV100300940; called by muse, varscan2
- LMAN1L | c.379G>A p.G127R | Missense Mutation (SNP) | VAF 321/506 reads (63%) | SIFT tolerated (0.07); PolyPhen benign (0.037); catalogued as rs1490407403, COSV100547563, COSV59000516; called by muse, mutect2, varscan2
- LMO7 | c.2482C>T p.P828S (on ENST00000357063; = p.P509S on NM_005358.5) | Missense Mutation (SNP) | VAF 278/443 reads (63%) | SIFT tolerated (0.17); PolyPhen benign (0.02); catalogued as COSV58548693; called by muse, mutect2, varscan2
- LONRF3 | c.1541C>T p.S514L (on ENST00000371628 / NM_001031855.3; = p.S473L on NM_024778.5) | Missense Mutation (SNP) | VAF 120/297 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.179); catalogued as COSV59151998; called by muse, mutect2, varscan2
- LPA | c.2570C>T p.S857L | Missense Mutation (SNP) | VAF 298/342 reads (87%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as rs771367882, COSV60310019; called by muse, mutect2
- LPAR4 | c.860G>A p.R287K | Missense Mutation (SNP) | VAF 161/659 reads (24%) | SIFT tolerated (0.67); PolyPhen benign (0.295); catalogued as COSV101425177; called by muse, mutect2, varscan2
- LRFN2 | c.2078C>T p.S693L | Missense Mutation (SNP) | VAF 248/1434 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.142); catalogued as rs369739868; called by muse, mutect2, varscan2
- LRP2 | c.13858C>T p.P4620S | Missense Mutation (SNP) | VAF 124/412 reads (30%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV55554203; called by muse, mutect2, varscan2
- LRP2 | c.12397G>A p.E4133K | Missense Mutation (SNP) | VAF 281/476 reads (59%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV55566677; called by muse, mutect2, varscan2
- LRP2 | c.2183C>T p.T728I | Missense Mutation (SNP) | VAF 20/434 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.019); catalogued as COSV99790043; called by muse, mutect2
- LRRC1 | c.706C>T p.P236S | Missense Mutation (SNP) | VAF 237/785 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63828325; called by muse, mutect2, varscan2
- LRRC17 | c.851G>A p.R284Q | Missense Mutation (SNP) | VAF 106/2046 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV50866822; called by muse, mutect2
- LY75 | c.992C>T p.S331F | Missense Mutation (SNP) | VAF 127/423 reads (30%) | SIFT tolerated (0.71); PolyPhen benign (0.026); catalogued as COSV55112579; called by muse, mutect2, varscan2
- M1AP | c.281C>T p.S94L | Missense Mutation (SNP) | VAF 225/647 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as COSV51844822; called by muse, mutect2, varscan2
- MAG | c.877G>A p.E293K | Missense Mutation (SNP) | VAF 202/902 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.415); catalogued as rs1476187963, COSV100727966; called by muse, varscan2
- MAGEB16 | c.26G>A p.R9Q | Missense Mutation (SNP) | VAF 482/976 reads (49%) | SIFT tolerated (0.7); PolyPhen benign (0.069); catalogued as rs746408660; called by muse, varscan2
- MAGEB18 | c.7C>T p.R3* | Nonsense Mutation (SNP) | VAF 86/496 reads (17%) | catalogued as rs1569246703; called by muse, mutect2, varscan2
- MAGEC1 | c.1921C>T p.P641S | Missense Mutation (SNP) | VAF 182/792 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.018); catalogued as COSV53577923, COSV53580970; called by muse, mutect2, varscan2
- MAGED2 | c.896C>T p.P299L | Missense Mutation (SNP) | VAF 266/574 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as COSV99514607; called by muse, mutect2, varscan2
- MAGEE1 | c.2195C>T p.S732F | Missense Mutation (SNP) | VAF 180/792 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.099); catalogued as rs1325796028; called by muse, varscan2
- MAGEL2 | c.490C>T p.P164S | Missense Mutation (SNP) | VAF 546/971 reads (56%) | SIFT deleterious, low confidence (0); catalogued as rs183812337, COSV58568463; called by muse, varscan2
- MAPK4 | c.209G>A p.R70Q | Missense Mutation (SNP) | VAF 316/1039 reads (30%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.558); catalogued as rs761581511, COSV68542087; called by muse, mutect2, varscan2
- MCF2 | c.412C>T p.R138C | Missense Mutation (SNP) | VAF 100/417 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as rs1267860187, COSV100644973, COSV58480427; called by muse, mutect2, varscan2
- MCF2L | c.1112C>T p.S371F (on ENST00000375608; = p.S339F on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 91/324 reads (28%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.616); catalogued as COSV65050664; called by muse, mutect2, varscan2
- MEGF8 | c.5776C>T p.R1926* (on ENST00000251268 / NM_001271938.2; = p.R1859* on NM_001410.3) | Nonsense Mutation (SNP) | VAF 532/751 reads (71%) | catalogued as COSV52101755; called by muse, mutect2, varscan2
- MET | c.2402G>A p.C801Y | Missense Mutation (SNP) | VAF 960/1306 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV59257645; called by muse, varscan2
- MGAM | c.1303G>A p.E435K | Missense Mutation (SNP) | VAF 265/533 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.398); catalogued as COSV72073548; called by muse, mutect2, varscan2
- MGAM2 | c.4012C>T p.P1338S | Missense Mutation (SNP) | VAF 152/958 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1351550217; called by muse, mutect2, varscan2
- MKRN3 | c.97C>T p.P33S | Missense Mutation (SNP) | VAF 161/519 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.42); catalogued as COSV58809034; called by muse, mutect2, varscan2
- MME | c.1915-1G>A p.X639_splice | Splice Site (SNP) | VAF 249/329 reads (76%) | catalogued as COSV64710727; called by muse, mutect2, varscan2
- MME | c.2154G>A p.R718= | Splice Region (SNP) | VAF 72/395 reads (18%) | catalogued as COSV64706287; called by muse, varscan2
- MMP23B | c.958C>T p.R320C | Missense Mutation (SNP) | VAF 83/460 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs1435936760; called by muse, mutect2, varscan2
- MMP28 | c.631C>T p.P211S | Missense Mutation (SNP) | VAF 542/544 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs1033215349; called by muse, varscan2
- MMP7 | c.518G>A p.G173E | Missense Mutation (SNP) | VAF 109/256 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1010094931; called by muse, mutect2, varscan2
- MOG | c.344G>A p.R115Q | Missense Mutation (SNP) | VAF 370/1188 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.028); catalogued as rs376255591; called by muse, varscan2
- MORF4L2 | c.209G>A p.G70E | Missense Mutation (SNP) | VAF 355/819 reads (43%) | SIFT tolerated (0.63); PolyPhen benign (0.015); catalogued as rs763870312; called by muse, mutect2, varscan2
- MOV10L1 | c.3068G>A p.G1023D | Missense Mutation (SNP) | VAF 300/745 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748978745; called by muse, mutect2, varscan2
- MRC1 | c.1244G>A p.G415E | Missense Mutation (SNP) | VAF 82/298 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as rs1554840488; called by muse, mutect2
- MRC2 | c.2700C>T p.F900= | Splice Region (SNP) | VAF 431/950 reads (45%) | catalogued as COSV57645646; called by muse, varscan2
- MRC2 | c.3814C>T p.P1272S | Missense Mutation (SNP) | VAF 425/966 reads (44%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.584); catalogued as COSV57641589; called by muse, mutect2, varscan2
- MRGPRX1 | c.571C>T p.L191F | Missense Mutation (SNP) | VAF 272/671 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as rs1368499311, COSV57107436; called by muse, varscan2
- MROH2B | c.3874G>A p.E1292K | Missense Mutation (SNP) | VAF 278/512 reads (54%) | SIFT deleterious (0.04); PolyPhen benign (0.135); catalogued as COSV68183148; called by muse, varscan2
- MRTFA | c.391C>T p.R131C | Missense Mutation (SNP) | VAF 407/764 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.247); catalogued as rs772930139, COSV62931401, COSV62932866; called by muse, varscan2
- MSH4 | c.1297C>T p.P433S | Missense Mutation (SNP) | VAF 91/313 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.178); catalogued as COSV54197607; called by muse, mutect2, varscan2
- MUC12 | c.1039G>A p.D347N (on ENST00000379442; = p.D204N on NM_001164462.1) | Missense Mutation (SNP) | VAF 339/2774 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as rs778509336; called by muse, mutect2, varscan2
- MUC16 | c.32026G>A p.E10676K | Missense Mutation (SNP) | VAF 356/492 reads (72%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.028); catalogued as COSV67491904; called by muse, varscan2
- MUC16 | c.29087G>A p.G9696E | Missense Mutation (SNP) | VAF 92/498 reads (18%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.007); catalogued as COSV67482472; called by muse, mutect2, varscan2
- MUC16 | c.29086G>A p.G9696R | Missense Mutation (SNP) | VAF 92/501 reads (18%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.042); catalogued as COSV67467789; called by muse, mutect2, varscan2
- MUC16 | c.22012G>A p.E7338K | Missense Mutation (SNP) | VAF 321/456 reads (70%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.027); catalogued as COSV67481394; called by muse, mutect2, varscan2
- MUC16 | c.11686G>T p.E3896* | Nonsense Mutation (SNP) | VAF 110/546 reads (20%) | catalogued as COSV67456265, COSV67475926; called by muse, mutect2, varscan2
- MUC16 | c.3683C>T p.S1228L | Missense Mutation (SNP) | VAF 315/641 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.895); catalogued as rs778561167, COSV67465815; called by muse, mutect2, varscan2
- MUC16 | c.1336G>A p.G446R | Missense Mutation (SNP) | VAF 126/556 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV101198439, COSV67470021; called by muse, mutect2, varscan2
- MUC4 | c.1970C>T p.P657L | Missense Mutation (SNP) | VAF 1016/1315 reads (77%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.722); catalogued as rs112809413; called by muse, mutect2, varscan2
- MUC6 | c.3034G>A p.D1012N | Missense Mutation (SNP) | VAF 277/864 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762847721; called by muse, varscan2
- MUL1 | c.176C>T p.P59L | Missense Mutation (SNP) | VAF 57/383 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.652); catalogued as rs1421654305; called by muse, mutect2, varscan2
- MYCBPAP | c.430G>A p.D144N | Missense Mutation (SNP) | VAF 406/848 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100089296; called by muse, varscan2
- MYH15 | c.2776C>T p.Q926* | Nonsense Mutation (SNP) | VAF 570/726 reads (79%) | catalogued as rs1443942160; called by muse, varscan2
- MYH4 | c.1504G>A p.E502K | Missense Mutation (SNP) | VAF 667/668 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV55117438; called by muse, mutect2, varscan2
- MYH7 | c.3847G>A p.E1283K | Missense Mutation (SNP) | VAF 205/548 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV62520880; called by muse, varscan2
- MYO16 | c.2812G>A p.E938K | Missense Mutation (SNP) | VAF 81/312 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as COSV51788523; called by muse, mutect2, varscan2
- MYO16 | c.3863G>A p.S1288N | Missense Mutation (SNP) | VAF 220/818 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.081); catalogued as rs1344542223, COSV62757539; called by muse, varscan2
- MYOCD | c.1194G>A p.M398I | Missense Mutation (SNP) | VAF 450/451 reads (100%) | SIFT tolerated (1); PolyPhen benign (0.022); catalogued as rs774560419, COSV58513540; called by muse, mutect2, varscan2
- NAA60 | c.104C>T p.P35L | Missense Mutation (SNP) | VAF 79/295 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1472076803, COSV100692879; called by muse, mutect2, varscan2
- NAP1L4 | c.896C>T p.S299F | Missense Mutation (SNP) | VAF 86/404 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV65882197, COSV65882413; called by muse, mutect2, varscan2
- NCOA6 | c.2962C>T p.P988S | Missense Mutation (SNP) | VAF 451/630 reads (72%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.091); catalogued as COSV62864438, COSV62868209; called by muse, mutect2, varscan2
- NELL2 | c.2326G>A p.E776K | Missense Mutation (SNP) | VAF 130/420 reads (31%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.986); catalogued as rs369537621; called by muse, varscan2
- NEUROD4 | c.916G>A p.D306N | Missense Mutation (SNP) | VAF 186/538 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.02); catalogued as rs774478814, COSV54474018; called by muse, varscan2
- NEXMIF | c.2293C>T p.P765S | Missense Mutation (SNP) | VAF 275/606 reads (45%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV50057480; called by muse, mutect2, varscan2
- NFAM1 | c.589G>T p.D197Y | Missense Mutation (SNP) | VAF 524/928 reads (56%) | SIFT tolerated (0.06); PolyPhen benign (0.037); catalogued as COSV61195448; called by muse, varscan2
- NFATC1 | c.256C>T p.P86S | Missense Mutation (SNP) | VAF 462/1459 reads (32%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.919); catalogued as rs765526389; called by muse, mutect2
- NFATC4 | c.682G>A p.E228K | Missense Mutation (SNP) | VAF 151/1015 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.054); catalogued as rs747668845, COSV51609189; called by muse, mutect2, varscan2
- NGEF | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 156/488 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.055); catalogued as rs143001761; called by muse, varscan2
- NHS | c.564G>A p.V188= | Splice Region (SNP) | VAF 296/628 reads (47%) | catalogued as rs368497497; called by muse, varscan2
- NLGN4X | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 258/556 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52011777, COSV52036003; called by muse, mutect2, varscan2
- NLRC3 | c.2601G>A p.L867= | Splice Region (SNP) | VAF 196/346 reads (57%) | catalogued as COSV57088083; called by muse, varscan2
- NLRP4 | c.1487G>A p.W496* | Nonsense Mutation (SNP) | VAF 486/670 reads (73%) | catalogued as COSV56712791; called by muse, varscan2
- NLRP9 | c.1564G>A p.E522K | Missense Mutation (SNP) | VAF 418/588 reads (71%) | SIFT deleterious (0.02); PolyPhen benign (0.145); catalogued as rs759340206, COSV60461331; called by muse, varscan2
- NOS3 | c.1024G>A p.E342K | Missense Mutation (SNP) | VAF 300/1097 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52492127; called by muse, mutect2, varscan2
- NOVA1 | c.413C>T p.P138L | Missense Mutation (SNP) | VAF 458/757 reads (61%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV57486207; called by muse, mutect2, varscan2
- NPPB | c.368C>T p.S123F | Missense Mutation (SNP) | VAF 139/692 reads (20%) | SIFT tolerated (0.75); PolyPhen benign (0.007); catalogued as COSV64687567; called by muse, mutect2, varscan2
- NPR2 | c.409C>T p.R137C | Missense Mutation (SNP) | VAF 580/582 reads (100%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.823); catalogued as COSV61313665; called by muse, varscan2
- NPY5R | c.1085G>A p.R362K | Missense Mutation (SNP) | VAF 162/255 reads (64%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.978); catalogued as COSV58452571; called by muse, mutect2, varscan2
- NREP | c.53G>A p.R18Q | Missense Mutation (SNP) | VAF 206/290 reads (71%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as rs1192701096, COSV67401246; called by muse, mutect2, varscan2
- NRG1 | c.242C>T p.P81L (on ENST00000523534; = p.P228L on NM_013962.2) | Missense Mutation (SNP) | VAF 488/673 reads (73%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1401083340; called by muse, varscan2
- NRP1 | c.2119C>T p.R707C | Missense Mutation (SNP) | VAF 134/440 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1376849398; called by muse, varscan2
- NXPH1 | c.358G>A p.G120R | Missense Mutation (SNP) | VAF 294/581 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101339580; called by muse, mutect2, varscan2
- NXPH3 | c.425G>A p.G142E | Missense Mutation (SNP) | VAF 203/521 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100165582; called by muse, mutect2, varscan2
- OBSCN | c.20249C>T p.S6750F | Missense Mutation (SNP) | VAF 258/259 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62367518; called by muse, mutect2, varscan2
- OCRL | c.1262G>A p.G421E | Missense Mutation (SNP) | VAF 174/401 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs137853855, CM002075; ClinVar: not provided; called by muse, mutect2, varscan2
- OGDHL | c.1486C>T p.R496C | Missense Mutation (SNP) | VAF 124/490 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370076789; called by muse, varscan2
- OGDHL | c.1319G>A p.R440Q | Missense Mutation (SNP) | VAF 107/512 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV65100576; called by muse, varscan2
- OLR1 | c.587C>T p.S196F | Missense Mutation (SNP) | VAF 138/402 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as rs267603272; called by muse, varscan2
- OPRK1 | c.1003G>A p.E335K | Missense Mutation (SNP) | VAF 137/808 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); catalogued as COSV55569167; called by muse, mutect2, varscan2
- OR10AG1 | c.416C>T p.S139F | Missense Mutation (SNP) | VAF 214/324 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV56635235; called by muse, mutect2, varscan2
- OR10G8 | c.575C>T p.S192L | Missense Mutation (SNP) | VAF 244/247 reads (99%) | SIFT tolerated (0.09); PolyPhen benign (0.047); catalogued as COSV70909429; called by muse, mutect2, varscan2
- OR10G9 | c.148G>A p.D50N | Missense Mutation (SNP) | VAF 164/598 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.053); catalogued as rs1206441063, COSV100901436; called by muse, varscan2
- OR10W1 | c.845C>T p.A282V | Missense Mutation (SNP) | VAF 93/288 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV67720794; called by muse, mutect2, varscan2
- OR14C36 | c.25G>A p.E9K | Missense Mutation (SNP) | VAF 94/295 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.434); catalogued as rs1351356830, COSV58601692; called by muse, mutect2, varscan2
- OR2A2 | c.184C>T p.L62F | Missense Mutation (SNP) | VAF 305/1512 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs761285796; called by muse, mutect2, varscan2
- OR2AJ1 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 136/375 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as rs866152293; called by muse, mutect2, varscan2
- OR2T12 | c.629C>T p.S210F | Missense Mutation (SNP) | VAF 546/556 reads (98%) | SIFT deleterious (0.03); PolyPhen benign (0.327); catalogued as COSV58775820; called by muse, mutect2, varscan2
- OR4A47 | c.823G>A p.V275I | Missense Mutation (SNP) | VAF 242/383 reads (63%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.09); catalogued as rs367667078; called by muse, mutect2, varscan2
- OR4A5 | c.70G>A p.A24T | Missense Mutation (SNP) | VAF 119/361 reads (33%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.015); catalogued as rs570062308, COSV100157166; called by muse, mutect2, varscan2
- OR4C6 | c.844C>T p.P282S | Missense Mutation (SNP) | VAF 96/327 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.323); catalogued as COSV58604690, COSV58606437; called by muse, mutect2, varscan2
- OR4D2 | c.801G>A p.M267I | Missense Mutation (SNP) | VAF 494/1010 reads (49%) | SIFT tolerated (0.21); PolyPhen benign (0.02); catalogued as COSV73459859; called by muse, varscan2
- OR4E2 | c.932C>T p.S311L | Missense Mutation (SNP) | VAF 132/362 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.052); catalogued as COSV57731425; called by muse, mutect2, varscan2
- OR4F6 | c.727C>T p.H243Y | Missense Mutation (SNP) | VAF 291/658 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.914); catalogued as rs1461540396, COSV61026980; called by muse, mutect2, varscan2
- OR5B12 | c.469C>T p.H157Y | Missense Mutation (SNP) | VAF 266/405 reads (66%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.029); catalogued as COSV56905030, COSV56906809; called by muse, mutect2, varscan2
- OR5D13 | c.227C>T p.S76F | Missense Mutation (SNP) | VAF 126/407 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as rs867480738, COSV100686785; called by muse, mutect2, varscan2
- OR6N1 | c.17G>A p.W6* | Nonsense Mutation (SNP) | VAF 305/306 reads (100%) | catalogued as COSV58650273; called by muse, varscan2
- OR8J3 | c.10G>A p.E4K | Missense Mutation (SNP) | VAF 154/268 reads (57%) | SIFT tolerated (0.92); PolyPhen benign (0.006); catalogued as COSV56882367; called by muse, varscan2
- OSBPL3 | c.1336G>A p.D446N | Missense Mutation (SNP) | VAF 206/509 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs779397050; called by muse, mutect2, varscan2
- OTOGL | c.5077G>A p.D1693N (on ENST00000547103; = p.D1684N on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 87/255 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764302483, COSV54015194, COSV54018068; called by muse, mutect2, varscan2
- OTOGL | c.5260G>A p.D1754N (on ENST00000547103; = p.D1745N on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 123/194 reads (63%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs1429518056; called by muse, varscan2
- PACS2 | c.247C>T p.P83S | Missense Mutation (SNP) | VAF 335/536 reads (63%) | SIFT tolerated (0.07); PolyPhen benign (0.03); catalogued as COSV57655992; called by muse, mutect2, varscan2
- PADI4 | c.1802C>G p.P601R | Missense Mutation (SNP) | VAF 284/380 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64924071; called by muse, varscan2
- PARP8 | c.2042C>T p.S681F | Missense Mutation (SNP) | VAF 83/397 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as COSV99892335; called by muse, mutect2, varscan2
- PARP8 | c.2197C>T p.L733F | Missense Mutation (SNP) | VAF 78/314 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.773); catalogued as rs1281381538; called by muse, varscan2
- PASD1 | c.2017C>T p.P673S | Missense Mutation (SNP) | VAF 423/952 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.052); catalogued as COSV64855689; called by muse, mutect2, varscan2
- PBRM1 | c.4960A>G p.K1654E (on ENST00000296302 / NM_001366071.2; = p.K1547E on NM_018313.5) | Missense Mutation (SNP) | VAF 492/652 reads (75%) | SIFT tolerated (0.13); PolyPhen benign (0.396); catalogued as COSV56290572; called by muse, mutect2, varscan2
- PCDH15 | c.3009G>A p.K1003= | Splice Region (SNP) | VAF 188/260 reads (72%) | catalogued as rs1478490847; called by muse, varscan2
- PCDH15 | c.2290C>T p.R764C | Missense Mutation (SNP) | VAF 121/495 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.849); catalogued as rs192813057, COSV57279849; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PCDH15 | c.1645C>T p.L549F | Missense Mutation (SNP) | VAF 114/453 reads (25%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); catalogued as COSV57312185, COSV57372906; called by muse, mutect2, varscan2
- PCDH8 | c.988G>A p.G330R | Missense Mutation (SNP) | VAF 544/876 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58811305; called by muse, varscan2
- PCDHA2 | c.949G>A p.E317K | Missense Mutation (SNP) | VAF 214/314 reads (68%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.147); catalogued as rs17844246, COSV65366110; called by muse, varscan2
- PCDHGB3 | c.1517C>T p.S506F | Missense Mutation (SNP) | VAF 188/813 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54030946; called by muse, varscan2
- PCLO | c.11477G>A p.G3826E | Missense Mutation (SNP) | VAF 343/1704 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61653210, COSV61660273; called by muse, mutect2, varscan2
- PCLO | c.4630G>A p.E1544K | Missense Mutation (SNP) | VAF 307/1407 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.019); catalogued as COSV61656062; called by muse, mutect2, varscan2
- PCNX2 | c.1475C>T p.S492L | Missense Mutation (SNP) | VAF 241/392 reads (61%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.017); catalogued as rs181942130; called by muse, mutect2, varscan2
- PCP4L1 | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 285/285 reads (100%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.953); catalogued as rs1253772768, COSV73440577; called by muse, mutect2, varscan2
- PDE1A | c.893G>A p.R298Q | Missense Mutation (SNP) | VAF 232/363 reads (64%) | SIFT deleterious (0.01); PolyPhen benign (0.418); catalogued as rs760883561; called by muse, varscan2
- PDLIM1 | c.460G>A p.E154K | Missense Mutation (SNP) | VAF 135/511 reads (26%) | SIFT tolerated (0.43); PolyPhen benign (0.342); catalogued as COSV61473837; called by muse, mutect2, varscan2
- PDXDC1 | c.1906G>A p.G636R | Missense Mutation (SNP) | VAF 171/566 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765071919; called by muse, varscan2
- PELI1 | c.952C>T p.H318Y | Missense Mutation (SNP) | VAF 243/677 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV62730337; called by muse, mutect2, varscan2
- PGC | c.359C>T p.S120L | Missense Mutation (SNP) | VAF 436/738 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs768314678, COSV63123835; called by muse, varscan2
- PHC2 | c.168del p.V57Cfs*3 | Frame Shift Del (DEL) | VAF 69/332 reads (21%) | catalogued as COSV57106610; called by mutect2, pindel, varscan2
- PHETA1 | c.625C>T p.R209C | Missense Mutation (SNP) | VAF 573/886 reads (65%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.749); catalogued as rs778775900; called by muse, mutect2, varscan2
- PHEX | c.1837G>A p.E613K | Missense Mutation (SNP) | VAF 86/469 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.084); catalogued as COSV65079438; called by muse, varscan2
- PHF20 | c.70C>T p.R24C | Missense Mutation (SNP) | VAF 251/344 reads (73%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs746538790; called by muse, varscan2
- PHKA1 | c.1282C>T p.R428C | Missense Mutation (SNP) | VAF 230/474 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59804362; called by muse, mutect2, varscan2
- PI16 | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 128/847 reads (15%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.532); catalogued as rs749242578, COSV65447997, COSV65448409; called by muse, mutect2, varscan2
- PIEZO2 | c.3127G>A p.E1043K | Missense Mutation (SNP) | VAF 262/808 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.039); catalogued as rs898421844; called by muse, varscan2
- PIK3C2G | c.4400G>A p.R1467Q (on ENST00000676171; = p.R1426Q on NM_004570.5) | Missense Mutation (SNP) | VAF 116/361 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs767127006; called by muse, mutect2, varscan2
- PITX1 | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 270/402 reads (67%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.018); catalogued as rs748627311; called by muse, varscan2
- PKD1 | c.3818C>T p.T1273I | Missense Mutation (SNP) | VAF 458/764 reads (60%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as rs933551615; called by muse, varscan2
- PKD1L1 | c.8492C>T p.P2831L | Missense Mutation (SNP) | VAF 238/490 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.236); catalogued as rs1358665703; called by muse, mutect2, varscan2
- PKD1L3 | c.580C>T p.H194Y | Missense Mutation (SNP) | VAF 98/142 reads (69%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs371937366; called by muse, mutect2, varscan2
- PKHD1L1 | c.6157G>A p.E2053K | Missense Mutation (SNP) | VAF 71/452 reads (16%) | SIFT tolerated (0.8); PolyPhen benign (0.006); catalogued as rs1207349530, COSV65747449; called by muse, varscan2
- PKP2 | c.907G>A p.E303K | Missense Mutation (SNP) | VAF 338/538 reads (63%) | SIFT tolerated (0.15); PolyPhen benign (0.214); catalogued as COSV50731382; called by muse, varscan2
- PLAC1 | c.484G>A p.D162N | Missense Mutation (SNP) | VAF 183/762 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.062); catalogued as rs200146015, COSV63656850; called by muse, mutect2, varscan2
- PLCB1 | c.2731G>A p.E911K | Missense Mutation (SNP) | VAF 59/301 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as rs1364886743, COSV62042906; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLCG2 | c.674C>T p.S225L | Missense Mutation (SNP) | VAF 88/310 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.181); catalogued as rs770601419, COSV100842743, COSV63869239, COSV63873402; called by muse, mutect2, varscan2
- PLCL2 | c.985G>A p.E329K (on ENST00000615277 / NM_001144382.2; = p.E203K on NM_015184.5) | Missense Mutation (SNP) | VAF 420/557 reads (75%) | SIFT tolerated (0.18); PolyPhen benign (0.271); catalogued as COSV67624935; called by muse, mutect2, varscan2
- PLCZ1 | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 200/320 reads (63%) | SIFT tolerated (0.28); PolyPhen benign (0.13); catalogued as COSV56854309; called by muse, mutect2, varscan2
- PLEKHA6 | c.1604G>A p.G535E | Missense Mutation (SNP) | VAF 302/303 reads (100%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV55340245; called by muse, varscan2
- PLEKHN1 | c.1643C>T p.P548L (on ENST00000379409; = p.P496L on NM_032129.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 167/1118 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.039); catalogued as COSV58022597; called by muse, varscan2
- PLXNB3 | c.953C>T p.P318L | Missense Mutation (SNP) | VAF 463/1107 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.659); catalogued as COSV62795753; called by muse, varscan2
- PODN | c.274G>A p.E92K (on ENST00000395871; = p.E44K on NM_153703.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 900/1158 reads (78%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.982); catalogued as rs769165495, COSV57010995; called by muse, varscan2
- POF1B | c.726G>A p.V242= | Splice Region (SNP) | VAF 183/363 reads (50%) | catalogued as rs879091306, COSV99427446; called by muse, varscan2
- POMGNT2 | c.710C>T p.S237F | Missense Mutation (SNP) | VAF 315/783 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1034936858; called by muse, mutect2, varscan2
- PPFIA2 | c.835A>G p.K279E | Missense Mutation (SNP) | VAF 225/359 reads (63%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); catalogued as COSV61020153; called by muse, mutect2, varscan2
- PPFIA2 | c.193G>A p.D65N | Missense Mutation (SNP) | VAF 75/294 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV61030769; called by muse, mutect2, varscan2
- PPIA | c.109C>T p.R37C | Missense Mutation (SNP) | VAF 180/382 reads (47%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.018); catalogued as rs1164610556, COSV63534314; called by muse, varscan2
- PPM1J | c.77C>T p.P26L | Missense Mutation (SNP) | VAF 468/636 reads (74%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.029); catalogued as rs775583142; called by mutect2, varscan2
- PPP1R13L | c.2357C>T p.T786I | Missense Mutation (SNP) | VAF 550/1109 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100714778; called by muse, mutect2, varscan2
- PPP1R14C | c.449G>A p.R150Q | Missense Mutation (SNP) | VAF 348/348 reads (100%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); catalogued as rs766379125, COSV100744829, COSV63173202; called by muse, varscan2
- PPP1R3A | c.2324C>T p.P775L | Missense Mutation (SNP) | VAF 312/1408 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.857); catalogued as COSV52889819, COSV99493725; called by muse, mutect2, varscan2
- PRAMEF1 | c.1111C>T p.P371S | Missense Mutation (SNP) | VAF 151/867 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as rs369455721; called by muse, mutect2
- PRAMEF11 | c.1100C>T p.S367F | Missense Mutation (SNP) | VAF 124/1149 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as COSV101463416; called by muse, varscan2
- PRKCI | c.1613C>T p.P538L | Missense Mutation (SNP) | VAF 81/414 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99856058; called by muse, mutect2, varscan2
- PRKN | c.338C>T p.P113L | Missense Mutation (SNP) | VAF 420/422 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as rs1404458540; called by muse, varscan2
- PROM2 | c.1409G>A p.G470E | Missense Mutation (SNP) | VAF 147/463 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751957720, COSV100468915; called by muse, mutect2, varscan2
- PSG2 | c.543G>A p.W181* | Nonsense Mutation (SNP) | VAF 116/531 reads (22%) | catalogued as COSV61545792; called by muse, mutect2, varscan2
- PSG6 | c.1288C>T p.Q430* | Nonsense Mutation (SNP) | VAF 316/440 reads (72%) | catalogued as rs1299318377; called by muse, mutect2, varscan2
- PSKH2 | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 1124/1384 reads (81%) | SIFT tolerated (0.84); PolyPhen benign (0.003); catalogued as COSV52609635; called by muse, varscan2
- PSMD2 | c.1986G>T p.M662I | Missense Mutation (SNP) | VAF 124/691 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.48); catalogued as rs781306544; called by muse, mutect2, varscan2
- PTPN22 | c.183G>T p.K61N | Missense Mutation (SNP) | VAF 235/306 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63086374; called by mutect2, varscan2
- PTPRB | c.944G>A p.G315E | Missense Mutation (SNP) | VAF 134/458 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54250520; called by muse, varscan2
- PTPRB | c.662C>T p.S221F | Missense Mutation (SNP) | VAF 104/345 reads (30%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.954); catalogued as COSV99718708; called by muse, mutect2, varscan2
- PTPRK | c.3526G>A p.E1176K (on ENST00000368215 / NM_001291984.2; = p.E1177K on NM_002844.4) | Missense Mutation (SNP) | VAF 97/289 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV63890744, COSV63895574; called by muse, mutect2, varscan2
- PTPRQ | c.4534C>T p.R1512C (on ENST00000616559; = p.R1470C on NM_001145026.2) | Missense Mutation (SNP) | VAF 203/338 reads (60%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); catalogued as rs769414150, COSV57044324; called by muse, mutect2, varscan2
- PTPRT | c.3796G>A p.D1266N | Missense Mutation (SNP) | VAF 462/628 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs779663880, COSV61962183; called by muse, varscan2
- PTPRZ1 | c.6590C>T p.P2197L | Missense Mutation (SNP) | VAF 345/622 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs759137152; called by muse, mutect2, varscan2
- PXDNL | c.4316C>T p.P1439L | Missense Mutation (SNP) | VAF 94/564 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.098); catalogued as rs1345639960, COSV100685712, COSV100687045; called by muse, mutect2
- PXDNL | c.1843C>G p.L615V | Missense Mutation (SNP) | VAF 126/737 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs1460757004, COSV62494809; called by muse, mutect2, varscan2
- RAD51AP2 | c.792G>A p.M264I | Missense Mutation (SNP) | VAF 212/574 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV67588482; called by muse, mutect2, varscan2
- RANBP3L | c.1115G>A p.R372Q | Missense Mutation (SNP) | VAF 286/654 reads (44%) | SIFT tolerated (0.34); PolyPhen benign (0.018); catalogued as rs773106667; called by muse, varscan2
- RASGRP4 | c.1255G>A p.E419K | Missense Mutation (SNP) | VAF 387/544 reads (71%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as rs1400890346; called by muse, varscan2
- RBBP6 | c.4297C>T p.R1433C | Missense Mutation (SNP) | VAF 252/386 reads (65%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.513); catalogued as rs1490786927, COSV60503810; called by muse, varscan2
- RBPJL | c.307G>A p.V103M | Missense Mutation (SNP) | VAF 147/602 reads (24%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.564); catalogued as COSV59212775; called by muse, mutect2, varscan2
- RBSN | c.1325G>C p.G442A | Missense Mutation (SNP) | VAF 636/853 reads (75%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV53795003; called by muse, mutect2, varscan2
- RELN | c.7387C>T p.P2463S | Missense Mutation (SNP) | VAF 201/1879 reads (11%) | SIFT tolerated (0.45); PolyPhen benign (0.005); catalogued as rs865938622; called by muse, mutect2, varscan2
- RET | c.3145C>T p.P1049S | Missense Mutation (SNP) | VAF 151/646 reads (23%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.999); catalogued as COSV100394920; called by muse, mutect2, varscan2
- RHCE | c.770C>T p.S257F | Missense Mutation (SNP) | VAF 520/730 reads (71%) | SIFT deleterious (0); PolyPhen benign (0.019); catalogued as COSV53802074; called by muse, varscan2
- RICTOR | c.3077C>T p.S1026L | Missense Mutation (SNP) | VAF 280/780 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs752956118; called by muse, mutect2, varscan2
- RLIM | c.1109C>T p.S370F | Missense Mutation (SNP) | VAF 361/732 reads (49%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.996); catalogued as rs778391559; called by muse, mutect2, varscan2
- RNF123 | c.491T>C p.V164A | Missense Mutation (SNP) | VAF 77/411 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV59691146; called by muse, mutect2, varscan2
- RNF180 | c.210G>A p.W70* | Nonsense Mutation (SNP) | VAF 248/336 reads (74%) | catalogued as rs770108803; called by muse, mutect2, varscan2
- RNF217 | c.245G>A p.R82Q | Missense Mutation (SNP) | VAF 729/731 reads (100%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0); catalogued as COSV101451395; called by muse, mutect2, varscan2
- RP1 | c.2380G>A p.E794K | Missense Mutation (SNP) | VAF 66/385 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.089); catalogued as rs749195619, COSV104377682; called by muse, mutect2, varscan2
- RP1 | c.4627G>A p.D1543N | Missense Mutation (SNP) | VAF 368/465 reads (79%) | SIFT deleterious (0); PolyPhen benign (0.192); catalogued as COSV55116509; called by muse, mutect2, varscan2
- RP2 | c.949G>A p.E317K | Missense Mutation (SNP) | VAF 220/534 reads (41%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs782721235, COSV54462553; ClinVar: benign; called by muse, varscan2
- RPAP1 | c.3670G>A p.G1224R | Missense Mutation (SNP) | VAF 290/472 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs377451240; called by muse, varscan2
- RPE65 | c.371G>A p.R124Q | Missense Mutation (SNP) | VAF 88/467 reads (19%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as rs748546353, COSV52013547, COSV52015838, COSV52016741; called by muse, mutect2, varscan2
- RPS6KA2 | c.1849G>A p.D617N | Missense Mutation (SNP) | VAF 347/347 reads (100%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.992); catalogued as rs1198195311, COSV55815902; called by muse, varscan2
- RPTN | c.1069C>T p.Q357* | Nonsense Mutation (SNP) | VAF 154/459 reads (34%) | catalogued as COSV100285868; called by muse, mutect2, varscan2
- RTL1 | c.2683G>A p.D895N | Missense Mutation (SNP) | VAF 253/751 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs561955511, COSV66017312; called by muse, mutect2, varscan2
- RTN1 | c.1039G>A p.G347R | Missense Mutation (SNP) | VAF 233/409 reads (57%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as COSV50718640; called by muse, mutect2, varscan2
- RTN4R | c.637C>T p.R213C | Missense Mutation (SNP) | VAF 548/1391 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as rs764343548, COSV50381942; called by muse, varscan2
- RUNX1 | c.1028C>T p.A343V (on ENST00000344691 / NM_001001890.3; = p.A370V on NM_001754.5) | Missense Mutation (SNP) | VAF 216/940 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.098); catalogued as rs1457932375; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RXFP2 | c.1097C>T p.P366L | Missense Mutation (SNP) | VAF 99/324 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.197); catalogued as rs267603799; called by muse, mutect2, varscan2
- RXFP2 | c.1423G>A p.D475N | Missense Mutation (SNP) | VAF 170/281 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1243388453, COSV53637789; called by muse, mutect2, varscan2
- RYR3 | c.2457G>A p.M819I | Missense Mutation (SNP) | VAF 131/403 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.239); catalogued as COSV66809818; called by muse, mutect2, varscan2
- RYR3 | c.10181C>T p.S3394L (on ENST00000389232; = p.S3395L on NM_001036.6) | Missense Mutation (SNP) | VAF 145/278 reads (52%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs1442312090, COSV66803668; called by muse, mutect2, varscan2
- S100A7L2 | c.11C>T p.P4L | Missense Mutation (SNP) | VAF 218/358 reads (61%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs943172702, COSV100906869, COSV64194894; called by muse, varscan2
- SALL3 | c.850G>A p.A284T | Missense Mutation (SNP) | VAF 85/254 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs937827552; called by muse, mutect2, varscan2
- SAMD7 | c.1201C>T p.P401S | Missense Mutation (SNP) | VAF 116/694 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.18); catalogued as COSV59416739; called by muse, mutect2, varscan2
- SAMD9L | c.1948G>A p.E650K | Missense Mutation (SNP) | VAF 421/788 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100560676; called by muse, mutect2, varscan2
- SCAND1 | c.311C>T p.P104L | Missense Mutation (SNP) | VAF 196/968 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1184291076; called by muse, varscan2
- SCAP | c.1337G>A p.R446Q | Missense Mutation (SNP) | VAF 348/474 reads (73%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.968); catalogued as rs1052387428; called by muse, varscan2
- SCARA5 | c.994C>T p.R332* | Nonsense Mutation (SNP) | VAF 87/437 reads (20%) | catalogued as rs1022788310, COSV57276036; called by muse, mutect2, varscan2
- SCG3 | c.962C>T p.P321L | Missense Mutation (SNP) | VAF 198/294 reads (67%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs539392045; called by muse, mutect2, varscan2
- SCN11A | c.5011G>A p.D1671N | Missense Mutation (SNP) | VAF 159/775 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.275); catalogued as rs767489166; called by muse, mutect2, varscan2
- SCN4A | c.2286G>A p.W762* | Nonsense Mutation (SNP) | VAF 119/885 reads (13%) | catalogued as rs1555603114, COSV101438649; called by muse, mutect2, varscan2
- SCN5A | c.3688G>T p.E1230* (on ENST00000333535 / NM_198056.3; = p.E1229* on NM_000335.5) | Nonsense Mutation (SNP) | VAF 77/353 reads (22%) | catalogued as rs779669888; called by muse, mutect2, varscan2
- SCNN1G | c.1780C>T p.P594S | Missense Mutation (SNP) | VAF 460/714 reads (64%) | SIFT tolerated (0.87); PolyPhen possibly damaging (0.834); catalogued as COSV55602218; called by muse, varscan2
- SCO1 | c.803G>A p.G268E | Missense Mutation (SNP) | VAF 476/477 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV104370749; called by muse, mutect2, varscan2
- SCUBE1 | c.1696G>A p.E566K | Missense Mutation (SNP) | VAF 204/796 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs372229798; called by muse, varscan2
- SEC31B | c.2738C>T p.S913F | Missense Mutation (SNP) | VAF 166/653 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.052); catalogued as COSV64845724; called by muse, varscan2
- SEPTIN3 | c.41C>T p.S14L | Missense Mutation (SNP) | VAF 451/782 reads (58%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.514); catalogued as rs773006308; called by muse, mutect2, varscan2
- SERPINA7 | c.1102C>T p.P368S | Missense Mutation (SNP) | VAF 300/670 reads (45%) | SIFT tolerated (0.35); PolyPhen benign (0.01); catalogued as rs778707647, COSV59665835; called by muse, varscan2
- SERPINB2 | c.811G>A p.E271K | Missense Mutation (SNP) | VAF 240/742 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV55091593; called by muse, mutect2, varscan2
- SGCG | c.496C>T p.R166* | Nonsense Mutation (SNP) | VAF 54/184 reads (29%) | catalogued as COSV54557672, COSV54562563; called by muse, varscan2
- SGTB | c.550C>T p.P184S | Missense Mutation (SNP) | VAF 265/406 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1188020758; called by muse, varscan2
- SH3TC2 | c.2384C>T p.S795F | Missense Mutation (SNP) | VAF 348/471 reads (74%) | SIFT deleterious (0); PolyPhen benign (0.11); catalogued as COSV60463516; called by muse, mutect2, varscan2
- SH3TC2 | c.947G>C p.G316A | Missense Mutation (SNP) | VAF 307/428 reads (72%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1251082752; called by muse, mutect2, varscan2
- SHANK1 | c.1714G>A p.E572K | Missense Mutation (SNP) | VAF 148/666 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as rs368633151; called by muse, mutect2, varscan2
- SHISA3 | c.278-1G>A p.X93_splice | Splice Site (SNP) | VAF 199/200 reads (100%) | catalogued as COSV100069777; called by muse, mutect2, varscan2
- SHISA9 | c.409C>T p.R137C | Missense Mutation (SNP) | VAF 418/645 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV101376164, COSV69642083; called by muse, mutect2, varscan2
- SHOC1 | c.1567G>A p.D523N | Missense Mutation (SNP) | VAF 280/281 reads (100%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as rs755547424; called by muse, mutect2, varscan2
- SHOC1 | c.1075G>A p.E359K | Missense Mutation (SNP) | VAF 290/290 reads (100%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV59503954; called by muse, mutect2, varscan2
- SI | c.1882C>T p.P628S | Missense Mutation (SNP) | VAF 77/411 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.949); catalogued as rs764555878, COSV52297210; called by muse, mutect2, varscan2
- SIGLEC1 | c.2651C>T p.S884L | Missense Mutation (SNP) | VAF 99/449 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750926735; called by muse, mutect2, varscan2
- SIRPG | c.833C>T p.P278L | Missense Mutation (SNP) | VAF 145/567 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53806943; called by muse, mutect2, varscan2
- SKIV2L | c.1927C>T p.L643F | Missense Mutation (SNP) | VAF 376/1112 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs761742617, COSV64812591; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC12A3 | c.2561G>A p.R854K (on ENST00000563236 / NM_001126108.2; = p.R863K on NM_000339.3) | Missense Mutation (SNP) | VAF 86/293 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs8060046; called by muse, mutect2, varscan2
- SLC14A2 | c.1384C>T p.P462S | Missense Mutation (SNP) | VAF 348/592 reads (59%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV54912966; called by muse, mutect2, varscan2
- SLC16A12 | c.767C>T p.S256L | Missense Mutation (SNP) | VAF 116/472 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as rs1287452968, COSV57950501; called by muse, mutect2, varscan2
- SLC17A8 | c.1655C>T p.S552F | Missense Mutation (SNP) | VAF 117/414 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV60126629; called by muse, mutect2, varscan2
- SLC1A5 | c.1223C>T p.S408F | Missense Mutation (SNP) | VAF 407/570 reads (71%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.863); catalogued as COSV69467160, COSV69467166; called by muse, varscan2
- SLC22A5 | c.1364C>T p.P455L | Missense Mutation (SNP) | VAF 121/533 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM104592; called by muse, varscan2
- SLC24A3 | c.714-1G>A p.X238_splice | Splice Site (SNP) | VAF 104/490 reads (21%) | catalogued as COSV60110494; called by muse, mutect2, varscan2
- SLC26A7 | c.455C>T p.S152F | Missense Mutation (SNP) | VAF 274/506 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as COSV52590518; called by muse, mutect2, varscan2
- SLC2A7 | c.1471G>A p.E491K | Missense Mutation (SNP) | VAF 134/965 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.085); catalogued as COSV68901924; called by muse, mutect2, varscan2
- SLC36A2 | c.923C>T p.S308F | Missense Mutation (SNP) | VAF 338/452 reads (75%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV100079457; called by muse, mutect2, varscan2
- SLC45A1 | c.1156G>A p.D386N | Missense Mutation (SNP) | VAF 212/1256 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs200084739, COSV57092959; called by muse, varscan2
- SLC4A5 | c.2311C>T p.P771S | Missense Mutation (SNP) | VAF 159/460 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs866262420, COSV61025711; called by muse, mutect2, varscan2
- SLC4A9 | c.2467G>A p.G823R (on ENST00000507527 / NM_001258428.2; = p.G799R on NM_031467.3) | Missense Mutation (SNP) | VAF 257/355 reads (72%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV50184430; called by muse, varscan2
- SLC7A2 | c.637G>A p.G213R (on ENST00000494857 / NM_001370338.1; = p.G253R on NM_003046.6) | Missense Mutation (SNP) | VAF 466/662 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99135939; called by muse, varscan2
- SLC8A3 | c.964G>A p.D322N | Missense Mutation (SNP) | VAF 268/727 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.358); catalogued as COSV63524809; called by muse, mutect2, varscan2
- SLC8A3 | c.85C>T p.R29* | Nonsense Mutation (SNP) | VAF 272/692 reads (39%) | catalogued as rs889723304, COSV100775813, COSV63520541; called by muse, varscan2
- SLC9C2 | c.2194G>A p.D732N | Missense Mutation (SNP) | VAF 170/304 reads (56%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.911); catalogued as rs1456305392; called by muse, mutect2, varscan2
- SLIT1 | c.2498C>T p.S833F | Missense Mutation (SNP) | VAF 247/373 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs868277232, COSV104382514; called by muse, mutect2, varscan2
- SMC1B | c.316C>T p.R106C | Missense Mutation (SNP) | VAF 380/747 reads (51%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs748923396, COSV62529887; called by muse, varscan2
- SMCHD1 | c.1094C>T p.S365L | Missense Mutation (SNP) | VAF 162/276 reads (59%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs1178345431; called by muse, mutect2, varscan2
- SMO | c.1672G>A p.D558N | Missense Mutation (SNP) | VAF 100/763 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.013); catalogued as rs774627960, COSV104374869; called by muse, mutect2, varscan2
- SORCS3 | c.2153G>A p.R718K | Missense Mutation (SNP) | VAF 221/324 reads (68%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs776440027, COSV63799455; called by muse, mutect2, varscan2
- SORCS3 | c.2897C>T p.S966F | Missense Mutation (SNP) | VAF 308/424 reads (73%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.753); catalogued as COSV63794510; called by muse, varscan2
- SORD | c.574G>A p.A192T | Missense Mutation (SNP) | VAF 271/418 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs867888668; called by muse, varscan2
- SP140 | c.1712G>A p.R571Q | Missense Mutation (SNP) | VAF 164/285 reads (58%) | SIFT tolerated (0.4); PolyPhen benign (0.272); catalogued as rs201257053; called by muse, varscan2
- SPANXN3 | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 349/794 reads (44%) | SIFT tolerated, low confidence (0.17); PolyPhen probably damaging (0.991); catalogued as COSV65140742; called by muse, varscan2
- SPARCL1 | c.415G>A p.D139N | Missense Mutation (SNP) | VAF 448/450 reads (100%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.82); catalogued as rs140130359; called by muse, varscan2
- SPAST | c.614C>T p.S205F | Missense Mutation (SNP) | VAF 159/443 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.076); catalogued as COSV59512593; called by muse, mutect2, varscan2
- SPATA13 | c.1159C>T p.P387S | Missense Mutation (SNP) | VAF 87/263 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754626684; called by muse, mutect2, varscan2
- SPATA16 | c.1348C>T p.P450S | Missense Mutation (SNP) | VAF 304/390 reads (78%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV63528247; called by muse, mutect2, varscan2
- SPATA16 | c.406C>T p.R136C | Missense Mutation (SNP) | VAF 90/581 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.258); catalogued as rs144595913; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SPATA5L1 | c.1610C>T p.P537L | Missense Mutation (SNP) | VAF 204/335 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as rs776098345, COSV99972808; called by muse, mutect2, varscan2
- SPEG | c.8156C>T p.S2719F | Missense Mutation (SNP) | VAF 95/333 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.735); catalogued as COSV56674777; called by muse, mutect2, varscan2
- SPHKAP | c.4625G>A p.R1542Q | Missense Mutation (SNP) | VAF 84/282 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.081); catalogued as rs368367152, COSV60881066; called by muse, varscan2
- SPPL2A | c.364C>T p.P122S | Missense Mutation (SNP) | VAF 90/141 reads (64%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.446); catalogued as COSV55941481, COSV55943050; called by muse, varscan2
- SPSB4 | c.604C>T p.R202* | Nonsense Mutation (SNP) | VAF 405/921 reads (44%) | catalogued as COSV60150125; called by muse, mutect2, varscan2
- SPTB | c.4783G>A p.E1595K | Missense Mutation (SNP) | VAF 375/937 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs756327499, COSV67631249; called by muse, mutect2, varscan2
- SPTLC3 | c.347G>A p.R116K | Missense Mutation (SNP) | VAF 301/438 reads (69%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV100982956; called by muse, mutect2, varscan2
- SRL | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 118/454 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.131); catalogued as rs1295137726, COSV68423078; called by muse, mutect2
- ST6GALNAC5 | c.325C>T p.R109W | Missense Mutation (SNP) | VAF 154/778 reads (20%) | PolyPhen possibly damaging (0.67); catalogued as rs746598078, COSV59562032, COSV59564346; called by muse, varscan2
- ST6GALNAC5 | c.497C>T p.T166I | Missense Mutation (SNP) | VAF 404/1034 reads (39%) | PolyPhen possibly damaging (0.783); catalogued as COSV100602811; called by muse, varscan2
- ST8SIA4 | c.278G>A p.R93Q | Missense Mutation (SNP) | VAF 259/324 reads (80%) | PolyPhen probably damaging (0.988); catalogued as rs868733908, COSV51509166; called by muse, varscan2
- STARD9 | c.10643C>T p.A3548V | Missense Mutation (SNP) | VAF 154/454 reads (34%) | SIFT tolerated (0.57); PolyPhen benign (0.03); catalogued as rs1427752586; called by muse, mutect2, varscan2
- STC2 | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 65/292 reads (22%) | SIFT tolerated (0.72); PolyPhen possibly damaging (0.456); catalogued as rs143646937; called by muse, varscan2
- STXBP4 | c.1340C>T p.P447L | Missense Mutation (SNP) | VAF 166/406 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.046); catalogued as COSV100894674; called by muse, varscan2
- SVIL | c.4039G>A p.E1347K (on ENST00000355867 / NM_021738.3; = p.E921K on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 175/530 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.374); catalogued as COSV63442036; called by muse, mutect2, varscan2
- SYCP1 | c.1571C>T p.S524L | Missense Mutation (SNP) | VAF 329/437 reads (75%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV65698859; called by muse, mutect2, varscan2
- SYNE1 | c.21950C>T p.S7317F (on ENST00000367255 / NM_182961.4; = p.S7246F on NM_033071.3) | Missense Mutation (SNP) | VAF 186/481 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs981484025; called by muse, mutect2, varscan2
- SYNE1 | c.1468C>T p.H490Y (on ENST00000367255 / NM_182961.4; = p.H497Y on NM_033071.3) | Missense Mutation (SNP) | VAF 64/180 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.177); catalogued as COSV54897967; called by muse, varscan2
- SYNE3 | c.2701C>T p.P901S | Missense Mutation (SNP) | VAF 240/639 reads (38%) | SIFT tolerated (0.42); PolyPhen benign (0.015); catalogued as rs1354196722; called by muse, mutect2, varscan2
- SYT1 | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 81/286 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs138582600, COSV54034805; called by muse, mutect2, varscan2
- SYT10 | c.679G>A p.E227K | Missense Mutation (SNP) | VAF 266/415 reads (64%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs767119363, COSV57338723; called by muse, mutect2, varscan2
- SYT3 | c.1627G>A p.D543N | Missense Mutation (SNP) | VAF 217/940 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.248); catalogued as rs771552981; called by muse, mutect2, varscan2
- SYT4 | c.272C>T p.S91L | Missense Mutation (SNP) | VAF 492/805 reads (61%) | SIFT tolerated (0.14); PolyPhen benign (0.038); catalogued as COSV54903170; called by muse, varscan2
- TACC2 | c.8554-1G>A p.X2852_splice (on ENST00000334433; = p.X930_splice on NM_006997.4) | Splice Site (SNP) | VAF 222/326 reads (68%) | catalogued as COSV53278827, COSV99586836; called by muse, mutect2, varscan2
- TAOK2 | c.2830C>T p.P944S | Missense Mutation (SNP) | VAF 468/719 reads (65%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as COSV54238089; called by muse, mutect2, varscan2
- TAS1R2 | c.2251G>A p.E751K | Missense Mutation (SNP) | VAF 312/860 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV104428081; called by muse, varscan2
- TBC1D25 | c.560C>T p.S187L | Missense Mutation (SNP) | VAF 292/644 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.406); catalogued as COSV100952102; called by muse, varscan2
- TEF | c.827G>A p.R276Q | Missense Mutation (SNP) | VAF 540/986 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764930328; called by muse, varscan2
- TENM1 | c.6616G>A p.G2206R | Missense Mutation (SNP) | VAF 276/627 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV64431633; called by muse, mutect2, varscan2
- TEP1 | c.166C>T p.P56S | Missense Mutation (SNP) | VAF 481/833 reads (58%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.009); catalogued as rs939722304; called by muse, mutect2, varscan2
- TEPP | c.271G>A p.G91S | Missense Mutation (SNP) | VAF 210/360 reads (58%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.548); catalogued as rs539938986; called by muse, varscan2
- TESK1 | c.1430C>T p.P477L | Missense Mutation (SNP) | VAF 629/629 reads (100%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs756272696; called by muse, varscan2
- TET2 | c.4555G>A p.G1519R | Missense Mutation (SNP) | VAF 132/392 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as rs753711986; called by muse, varscan2
- TEX15 | c.4729A>C p.I1577L (on ENST00000256246; = p.I1960L on NM_001350162.2) | Missense Mutation (SNP) | VAF 92/423 reads (22%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV56341802; called by muse, mutect2, varscan2
- TFAP2D | c.1318G>A p.E440K | Missense Mutation (SNP) | VAF 334/505 reads (66%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.899); catalogued as rs778560524, COSV50407961; called by muse, mutect2, varscan2
- TGM2 | c.1922C>T p.P641L | Missense Mutation (SNP) | VAF 108/458 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); catalogued as rs776355908, COSV63932431; called by muse, varscan2
- TLE2 | c.1519C>T p.R507C | Missense Mutation (SNP) | VAF 204/281 reads (73%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); catalogued as rs1290850468, COSV99504510; called by muse, mutect2, varscan2
- TLNRD1 | c.629C>T p.S210L | Missense Mutation (SNP) | VAF 200/584 reads (34%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs769785232; called by muse, varscan2
- TMCC3 | c.263C>T p.S88L | Missense Mutation (SNP) | VAF 84/337 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.269); catalogued as rs144548464; called by muse, mutect2, varscan2
- TMCO2 | c.218G>A p.R73Q | Missense Mutation (SNP) | VAF 59/279 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.11); catalogued as rs750978469, COSV65646643; called by muse, mutect2, varscan2
- TMEM131L | c.547C>T p.H183Y | Missense Mutation (SNP) | VAF 58/218 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); catalogued as rs1419635686; called by muse, varscan2
- TMEM132C | c.1855G>A p.E619K | Missense Mutation (SNP) | VAF 143/471 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs1362798425; called by muse, mutect2, varscan2
- TMEM132C | c.2728G>A p.E910K | Missense Mutation (SNP) | VAF 194/608 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.392); catalogued as rs867717839, COSV59433766; called by muse, varscan2
- TMEM132D | c.2550G>A p.M850I | Missense Mutation (SNP) | VAF 168/520 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs377746256; called by muse, mutect2, varscan2
- TMEM211 | c.302G>A p.R101K (on ENST00000423535; = p.R30K on NM_001001663.3) | Missense Mutation (SNP) | VAF 406/1120 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as COSV66954153; called by muse, varscan2
- TMEM225 | c.547G>A p.E183K | Missense Mutation (SNP) | VAF 239/239 reads (100%) | SIFT tolerated (0.8); PolyPhen benign (0.003); catalogued as rs1310598409, COSV66692956; called by muse, mutect2, varscan2
- TMEM225 | c.258G>A p.M86I | Missense Mutation (SNP) | VAF 227/229 reads (99%) | SIFT deleterious (0.03); PolyPhen benign (0.039); catalogued as COSV66693518; called by muse, mutect2, varscan2
- TMIGD2 | c.476G>A p.G159E | Missense Mutation (SNP) | VAF 155/669 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1288484768, COSV56667322; called by muse, varscan2
- TNC | c.5699C>T p.S1900L | Missense Mutation (SNP) | VAF 302/303 reads (100%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.936); catalogued as rs775636762, COSV60782271; called by muse, mutect2, varscan2
- TNIK | c.2518G>A p.E840K | Missense Mutation (SNP) | VAF 635/819 reads (78%) | SIFT tolerated (0.05); PolyPhen benign (0.115); catalogued as rs767165156; called by muse, mutect2, varscan2
- TNK2 | c.2590G>A p.E864K | Missense Mutation (SNP) | VAF 772/964 reads (80%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as rs143850445, COSV100360813; called by muse, varscan2
- TNR | c.4001C>T p.P1334L | Missense Mutation (SNP) | VAF 375/375 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV54887612; called by muse, mutect2, varscan2
- TNRC18 | c.1001C>T p.P334L | Missense Mutation (SNP) | VAF 235/531 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs1006455062; called by muse, mutect2, varscan2
- TOX2 | c.1070G>A p.R357Q (on ENST00000358131 / NM_001098798.2; = p.R333Q on NM_032883.3) | Missense Mutation (SNP) | VAF 714/978 reads (73%) | SIFT tolerated (0.6); PolyPhen probably damaging (0.978); catalogued as rs773686339, COSV57882392; called by muse, mutect2, varscan2
- TPP1 | c.437C>T p.T146M | Missense Mutation (SNP) | VAF 131/463 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.139); catalogued as rs748686068, COSV100197018; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TPRX1 | c.670C>T p.P224S | Missense Mutation (SNP) | VAF 248/1104 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0.127); catalogued as rs201315320; called by muse, varscan2
- TRANK1 | c.2248G>A p.G750S | Missense Mutation (SNP) | VAF 666/850 reads (78%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs758736732; called by muse, mutect2, varscan2
- TREM1 | c.230C>T p.S77F | Missense Mutation (SNP) | VAF 315/977 reads (32%) | SIFT tolerated (0.73); PolyPhen possibly damaging (0.802); catalogued as COSV55149310; called by muse, mutect2, varscan2
- TREML2 | c.305G>A p.R102Q | Missense Mutation (SNP) | VAF 297/1248 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs762890750, COSV72438998; called by muse, varscan2
- TRIM55 | c.1174C>T p.P392S | Missense Mutation (SNP) | VAF 159/862 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.115); catalogued as CM146844; called by muse, mutect2, varscan2
- TRIM67 | c.985G>A p.E329K | Missense Mutation (SNP) | VAF 154/435 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.792); catalogued as rs891200251; called by muse, mutect2, varscan2
- TRIM77 | c.1318C>T p.P440S | Missense Mutation (SNP) | VAF 178/179 reads (99%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.986); catalogued as COSV68067283; called by muse, mutect2, varscan2
- TRMT10C | c.920A>G p.Y307C | Missense Mutation (SNP) | VAF 431/574 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1185897256; called by muse, mutect2, varscan2
- TRPC4 | c.1390C>T p.P464S | Missense Mutation (SNP) | VAF 84/307 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.038); catalogued as COSV59020701; called by muse, mutect2, varscan2
- TRPC6 | c.2431G>A p.G811R | Missense Mutation (SNP) | VAF 83/83 reads (100%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as COSV60252193; called by muse, mutect2, varscan2
- TRPC7 | c.916C>T p.P306S | Missense Mutation (SNP) | VAF 361/491 reads (74%) | SIFT tolerated (0.66); PolyPhen benign (0.015); catalogued as rs1211795803; called by muse, mutect2, varscan2
- TRPC7 | c.772G>A p.E258K | Missense Mutation (SNP) | VAF 60/259 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs773517278; called by muse, mutect2, varscan2
- TSHR | c.1286T>C p.L429P | Missense Mutation (SNP) | VAF 42/929 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as rs112833742; called by muse, mutect2
- TSHZ2 | c.2924C>T p.S975L | Missense Mutation (SNP) | VAF 296/715 reads (41%) | SIFT tolerated (0.46); PolyPhen benign (0.14); catalogued as rs267606003, COSV61586685; called by muse, varscan2
- TSSK1B | c.989G>A p.G330E | Missense Mutation (SNP) | VAF 143/574 reads (25%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs761618235; called by muse, mutect2, varscan2
- TSSK1B | c.385G>A p.D129N | Missense Mutation (SNP) | VAF 36/522 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.069); catalogued as rs753900877, COSV66814944; called by muse, mutect2
- TTLL2 | c.1312G>A p.D438N | Missense Mutation (SNP) | VAF 214/370 reads (58%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs748651103, COSV53445233; called by muse, mutect2, varscan2
- TTN | c.94933G>A p.E31645K (on ENST00000591111; = p.E24221K on NM_003319.4) | Missense Mutation (SNP) | VAF 129/249 reads (52%) | PolyPhen probably damaging (0.99); catalogued as rs780655169; called by muse, mutect2, varscan2
- TTN | c.75781C>T p.P25261S (on ENST00000591111; = p.P17837S on NM_003319.4) | Missense Mutation (SNP) | VAF 211/331 reads (64%) | PolyPhen possibly damaging (0.772); catalogued as rs1024262797; ClinVar: uncertain significance; called by muse, varscan2
- TTN | c.69268G>A p.E23090K (on ENST00000591111; = p.E15666K on NM_003319.4) | Missense Mutation (SNP) | VAF 140/421 reads (33%) | PolyPhen benign (0.298); catalogued as rs186780326, COSV59902383; called by muse, mutect2, varscan2
- TTN | c.56570C>T p.A18857V (on ENST00000591111; = p.A11433V on NM_003319.4) | Missense Mutation (SNP) | VAF 229/394 reads (58%) | PolyPhen possibly damaging (0.674); catalogued as rs145131899; called by muse, mutect2, varscan2
- TTN | c.54610C>T p.R18204C (on ENST00000591111; = p.R10780C on NM_003319.4) | Missense Mutation (SNP) | VAF 129/485 reads (27%) | PolyPhen benign (0.017); catalogued as rs1232069163, COSV60071060, COSV60191978; called by muse, mutect2, varscan2
- TTN | c.47836G>A p.E15946K (on ENST00000591111; = p.E8522K on NM_003319.4) | Missense Mutation (SNP) | VAF 126/423 reads (30%) | PolyPhen benign (0.098); catalogued as rs1271096467, COSV60231715; called by muse, mutect2, varscan2
- TTN | c.36412C>T p.P12138S (on ENST00000591111; = p.P4714S on NM_003319.4) | Missense Mutation (SNP) | VAF 171/255 reads (67%) | PolyPhen probably damaging (0.998); catalogued as COSV60379178; called by muse, mutect2, varscan2
- TTN | c.33914C>T p.P11305L (on ENST00000591111; = p.P10378L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 118/436 reads (27%) | PolyPhen benign (0); catalogued as rs574102745, COSV60164844; called by muse, varscan2
- TTN | c.14396G>A p.R4799Q (on ENST00000591111; = p.R3872Q on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 305/497 reads (61%) | PolyPhen possibly damaging (0.594); catalogued as rs769626460, COSV100629560; called by muse, mutect2, varscan2
- TTN | c.11059G>A p.E3687K (on ENST00000591111; = p.E3641K on NM_003319.4) | Missense Mutation (SNP) | VAF 145/459 reads (32%) | catalogued as rs755242569, COSV59954793; called by muse, varscan2
- TTN | c.6322G>A p.E2108K (on ENST00000591111; = p.E2062K on NM_003319.4) | Missense Mutation (SNP) | VAF 139/489 reads (28%) | PolyPhen probably damaging (0.994); catalogued as rs762999586, COSV60013101; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- TUBA3C | c.1097G>A p.G366E | Missense Mutation (SNP) | VAF 167/530 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.957); catalogued as rs868127144, COSV68029500; called by muse, varscan2
- TUBA3C | c.641G>A p.R214Q | Missense Mutation (SNP) | VAF 198/729 reads (27%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.037); catalogued as rs373201894, COSV67139696, COSV67139935; called by muse, varscan2
- UGT3A1 | c.1160G>A p.G387E | Missense Mutation (SNP) | VAF 547/1064 reads (51%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.81); catalogued as COSV57096535; called by muse, varscan2
- UNC13C | c.1046C>T p.S349L | Missense Mutation (SNP) | VAF 264/410 reads (64%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.014); catalogued as rs565877113, COSV52873149, COSV99509498; called by muse, varscan2
- UNC79 | c.3562C>T p.P1188S (on ENST00000393151 / NM_001346218.2; = p.P1011S on NM_020818.5) | Missense Mutation (SNP) | VAF 282/494 reads (57%) | SIFT tolerated (0.36); PolyPhen benign (0.334); catalogued as COSV56379087; called by muse, varscan2
- UNC93A | c.76C>T p.Q26* | Nonsense Mutation (SNP) | VAF 309/309 reads (100%) | catalogued as rs895339426; called by muse, mutect2, varscan2
- USH2A | c.188G>A p.R63Q | Missense Mutation (SNP) | VAF 275/275 reads (100%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs369806765, CM135886, COSV100240811; called by muse, mutect2, varscan2
- USP29 | c.154C>T p.Q52* | Nonsense Mutation (SNP) | VAF 230/476 reads (48%) | catalogued as COSV54237626; called by muse, varscan2
- USP29 | c.2572G>A p.D858N | Missense Mutation (SNP) | VAF 421/560 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756825168, COSV54140150, COSV54144117; called by muse, mutect2, varscan2
- VCX3A | c.269C>T p.P90L | Missense Mutation (SNP) | VAF 240/1446 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs781337353, COSV101129906; called by muse, varscan2
- VEGFD | c.253C>T p.R85W | Missense Mutation (SNP) | VAF 110/537 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs770666075; called by muse, mutect2, varscan2
- VN1R4 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 45/210 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.945); catalogued as COSV60805055; called by muse, mutect2, varscan2
- VPREB1 | c.58C>T p.Q20* | Nonsense Mutation (SNP) | VAF 448/806 reads (56%) | catalogued as COSV100164837; called by muse, mutect2, varscan2
1,780 further variants in this file (862 protein-altering or splice-affecting, 817 silent, 101 other) are not listed here.
